Somatic mutation profile of tumor specimen TCGA-WE-AAA0-06A (aliquot TCGA-WE-AAA0-06A-11D-A38G-08) from TCGA case TCGA-WE-AAA0, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 48.1 years (17,572 days).
Specimen TCGA-WE-AAA0-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 650e6da9-b2e9-4d9e-9ec3-7e2b962c84b9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-WE-AAA0-10A (Blood Derived Normal), aliquot TCGA-WE-AAA0-10A-01D-A38J-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fe75f068-6577-4237-83bb-fa8f6f6c8fa5

The open-access MAF lists 1,729 somatic variants for this specimen: 1,154 protein-altering or splice-affecting, 523 silent, 52 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1,053, Silent 523, Nonsense Mutation 63, Splice Region 16, RNA 15, Intron 15, Splice Site 12, 3'UTR 7, Frame Shift Del 6, 5'UTR 5, 3'Flank 5, 5'Flank 5.

Variants (750 of 1,729; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- CDK4 | c.64A>C p.K22Q | Missense Mutation (SNP) | VAF 39/70 reads (56%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1555201381, COSV56983663; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DICER1 | c.1525C>T p.R509* | Nonsense Mutation (SNP) | VAF 44/170 reads (26%) | catalogued as rs886037672, CM135357, COSV58621515; ClinVar: pathogenic; called by muse, mutect2, varscan2
- RHO | c.1021G>A p.E341K | Missense Mutation (SNP) | VAF 33/118 reads (28%) | SIFT tolerated (0.25); PolyPhen benign (0.251); catalogued as rs142322202, CD920908, CM014218, CM973327; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- ROBO2 | c.95G>A p.R32Q | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.907); catalogued as rs754279676, COSV59922580; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- AADACL2 | c.545G>A p.R182Q | Missense Mutation (SNP) | VAF 46/124 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs780021458, COSV62930020; called by muse, mutect2, varscan2
- AAR2 | c.310C>T p.P104S | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV100299406; called by muse, mutect2, varscan2
- ABCA10 | c.4024G>A p.E1342K | Missense Mutation (SNP) | VAF 59/175 reads (34%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.665); catalogued as COSV52227778, COSV99289243; called by muse, mutect2, varscan2
- ABCA2 | c.3817C>T p.R1273W (on ENST00000614293; = p.R1243W on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.54); catalogued as rs757119666, COSV99688333; called by muse, mutect2, varscan2
- ABCA8 | c.4465C>T p.H1489Y | Missense Mutation (SNP) | VAF 40/118 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV99286691; called by muse, mutect2, varscan2
- ABCC10 | c.3025C>T p.L1009F (on ENST00000372530 / NM_001198934.2; = p.L981F on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.622); catalogued as COSV99767869; called by muse, mutect2, varscan2
- ABCC6 | c.1638C>T p.V546= | Splice Region (SNP) | VAF 19/65 reads (29%) | catalogued as rs1011923791, COSV52741936; called by muse, mutect2, varscan2
- ABCC9 | c.3446T>C p.I1149T | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as COSV99686904; called by muse, mutect2, varscan2
- ABCC9 | c.3445A>C p.I1149L | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT tolerated (0.33); PolyPhen benign (0.044); catalogued as COSV99686911; called by muse, mutect2, varscan2
- ABCC9 | c.391C>T p.P131S | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.742); catalogued as rs751708268, COSV53989383; called by muse, mutect2, varscan2
- ABCG4 | c.356G>A p.R119K | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT tolerated (0.97); PolyPhen possibly damaging (0.492); catalogued as COSV56644615; called by muse, mutect2, varscan2
- ACAD10 | c.2156C>T p.P719L | Missense Mutation (SNP) | VAF 33/75 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.715); catalogued as COSV100564537; called by muse, mutect2, varscan2
- ACAN | c.2456C>T p.P819L | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.125); catalogued as COSV100719082; called by muse, mutect2
- ACSM3 | c.331C>T p.L111F | Missense Mutation (SNP) | VAF 33/89 reads (37%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.608); catalogued as COSV99184908; called by muse, mutect2, varscan2
- ACTRT2 | c.1003C>T p.P335S | Missense Mutation (SNP) | VAF 53/103 reads (51%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV101007654; called by muse, mutect2, varscan2
- ADA2 | c.1075G>A p.E359K (on ENST00000262607; = p.E118K on NM_177405.3) | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs749226595, COSV99376400; called by muse, mutect2, varscan2
- ADAD2 | c.1289C>T p.S430L (on ENST00000315906 / NM_001145400.2; = p.S512L on NM_139174.4) | Missense Mutation (SNP) | VAF 40/120 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.334); catalogued as rs753412548, COSV99235581; called by muse, mutect2, varscan2
- ADAM11 | c.2194G>A p.G732S | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.556); catalogued as rs1431631547, COSV52345163; called by muse, mutect2, varscan2
- ADAM19 | c.514G>A p.G172R | Missense Mutation (SNP) | VAF 64/111 reads (58%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.584); catalogued as COSV57426732; called by muse, mutect2, varscan2
- ADAMDEC1 | c.383G>A p.G128E | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs976542769, COSV99835917; called by muse, mutect2, varscan2
- ADAMTS18 | c.515G>A p.R172Q | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs770516167, COSV51399705; called by muse, mutect2, varscan2
- ADCY8 | c.3514G>A p.G1172R | Missense Mutation (SNP) | VAF 54/118 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99653954; called by muse, mutect2, varscan2
- ADD2 | c.1061C>A p.P354H | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.122); catalogued as COSV100036365; called by muse, mutect2, varscan2
- ADD2 | c.274G>A p.D92N | Missense Mutation (SNP) | VAF 28/105 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as COSV100036370; called by muse, mutect2, varscan2
- ADGRB3 | c.802C>T p.R268* | Nonsense Mutation (SNP) | VAF 6/32 reads (19%) | catalogued as COSV101001797; called by muse, mutect2, varscan2
- ADGRF5 | c.2707C>T p.P903S | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.026); catalogued as COSV51940978; called by muse, mutect2, varscan2
- ADGRG4 | c.3848C>T p.S1283F | Missense Mutation (SNP) | VAF 17/29 reads (59%) | SIFT tolerated (0.27); PolyPhen benign (0.086); catalogued as COSV54957590, COSV54966049; called by muse, mutect2, varscan2
- ADGRL2 | c.3501G>A p.M1167I | Missense Mutation (SNP) | VAF 28/67 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0.29); catalogued as COSV99591111; called by muse, mutect2, varscan2
- ADGRL3 | c.673G>A p.A225T (on ENST00000506720 / NM_001322402.2; = p.A157T on NM_015236.6) | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV101547372; called by muse, mutect2, varscan2
- ADGRV1 | c.3259C>T p.P1087S | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT tolerated (0.37); PolyPhen benign (0.033); catalogued as COSV101316392; called by muse, varscan2
- ADRA1A | c.908C>T p.P303L | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.752); catalogued as COSV99371944; called by muse, mutect2, varscan2
- AFF1 | c.833C>T p.S278F | Missense Mutation (SNP) | VAF 34/140 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.876); catalogued as COSV100321001; called by muse, mutect2, varscan2
- AGO1 | c.451C>T p.P151S | Missense Mutation (SNP) | VAF 19/93 reads (20%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs746713624, COSV64596221; called by muse, mutect2, varscan2
- AGPAT5 | c.1022G>A p.G341E | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV99576628; called by muse, mutect2, varscan2
- AGXT2 | c.1326G>A p.M442I | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV99183876; called by muse, mutect2, varscan2
- AK5 | c.131A>G p.K44R (on ENST00000354567 / NM_174858.3; = p.K18R on NM_012093.4) | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as rs765208716, COSV100481564; called by muse, mutect2, varscan2
- AKAP12 | c.2249C>T p.P750L | Missense Mutation (SNP) | VAF 39/140 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.826); catalogued as rs1562753892, COSV53572876; called by muse, mutect2, varscan2
- AKAP6 | c.784G>A p.E262K | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.339); catalogued as COSV55233084; called by muse, mutect2, varscan2
- AKAP6 | c.5516C>T p.P1839L | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0.036); catalogued as COSV99799806, COSV99799876; called by mutect2, varscan2
- AL662899.2 | c.202C>T p.Q68* | Nonsense Mutation (SNP) | VAF 14/60 reads (23%) | catalogued as COSV101021774; called by muse, mutect2, varscan2
- ALDH5A1 | c.1171A>G p.K391E | Missense Mutation (SNP) | VAF 28/89 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100708902; called by muse, mutect2, varscan2
- ALKBH1 | c.277C>T p.L93F | Missense Mutation (SNP) | VAF 63/187 reads (34%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.997); catalogued as COSV99380750; called by muse, mutect2, varscan2
- ALOXE3 | c.119G>A p.R40Q | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.207); catalogued as rs1209679604, COSV100503008; called by muse, mutect2
- ALPK2 | c.2854C>T p.P952S | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1251823435, COSV100864745; called by muse, mutect2, varscan2
- ALPK3 | c.2119G>A p.E707K | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT deleterious, low confidence (0.01); catalogued as COSV99361826; called by muse, mutect2, varscan2
- AMTN | c.620G>A p.G207E | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.084); catalogued as COSV59489674; called by muse, mutect2, varscan2
- ANK3 | c.7543C>T p.L2515F | Missense Mutation (SNP) | VAF 33/120 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.521); catalogued as rs1266079762, COSV55082059, COSV99781928; called by muse, mutect2, varscan2
- ANKIB1 | c.2698C>T p.P900S | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.007); catalogued as rs1485822377, COSV99729820; called by muse, mutect2
- ANKRD12 | c.5006C>T p.P1669L | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.015); catalogued as COSV50820002; called by muse, mutect2, varscan2
- ANKRD36B | c.1302G>A p.K434= | Splice Region (SNP) | VAF 9/38 reads (24%) | catalogued as COSV99308530; called by muse, varscan2
- ANO1 | c.2654C>T p.A885V | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT tolerated (0.24); PolyPhen benign (0.42); catalogued as COSV100797035; called by muse, mutect2, varscan2
- ANO3 | c.682A>C p.M228L | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT tolerated (0.31); PolyPhen benign (0.007); catalogued as COSV99885188; called by muse, mutect2, varscan2
- ANPEP | c.1868A>G p.N623S | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV100263448; called by muse, mutect2, varscan2
- AOAH | c.1672G>A p.E558K | Missense Mutation (SNP) | VAF 29/78 reads (37%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.452); catalogued as COSV99333619; called by muse, mutect2, varscan2
- AOC3 | c.1753C>T p.R585C | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.321); catalogued as rs199913475; called by muse, mutect2, varscan2
- AP2A1 | c.1272C>T p.I424= | Splice Region (SNP) | VAF 6/23 reads (26%) | catalogued as rs565962932, COSV62817682; called by muse, mutect2, varscan2
- AP2A2 | c.2381C>T p.S794F | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.378); catalogued as COSV100173268, COSV59960487; called by muse, mutect2, varscan2
- APOB | c.7765G>A p.E2589K | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.012); catalogued as COSV99267474; called by muse, mutect2, varscan2
- APOB | c.7227del p.F2409Lfs*15 | Frame Shift Del (DEL) | VAF 14/58 reads (24%) | catalogued as COSV51932895; called by mutect2, pindel, varscan2
- APOB | c.3702G>A p.M1234I | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV99267476; called by muse, mutect2, varscan2
- APOB | c.3374C>T p.S1125F | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.054); catalogued as COSV51942293; called by muse, mutect2
- ARFGEF3 | c.3773G>A p.R1258Q | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs771535333, COSV99294523; called by muse, varscan2
- ARHGAP26 | c.809G>T p.G270V | Missense Mutation (SNP) | VAF 23/43 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99191349; called by muse, mutect2, varscan2
- ARMC4 | c.2515G>T p.G839* | Nonsense Mutation (SNP) | VAF 18/51 reads (35%) | catalogued as COSV100536026; called by muse, mutect2, varscan2
- ARMC4 | c.257A>C p.K86T | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.052); catalogued as COSV53468795; called by muse, mutect2, varscan2
- ARRB2 | c.380C>T p.S127F | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs765964965, COSV52619205; called by muse, mutect2, varscan2
- ARRB2 | c.425G>A p.G142D | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52616399; called by muse, mutect2, varscan2
- ASAH2 | c.128-1G>A p.X43_splice | Splice Site (SNP) | VAF 6/13 reads (46%) | catalogued as COSV100270082; called by muse, mutect2, varscan2
- ASB16 | c.5C>A p.A2E | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as COSV99519033; called by muse, mutect2, varscan2
- ASGR2 | c.430G>A p.D144N | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.203); catalogued as rs373817872; called by muse, mutect2, varscan2
- ASXL3 | c.2381G>A p.G794E | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.001); catalogued as rs1432456447, COSV99326222; called by muse, mutect2, varscan2
- ATL1 | c.487G>A p.V163I | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT tolerated (0.7); PolyPhen benign (0.044); catalogued as COSV100613277; called by muse, mutect2, varscan2
- ATP10B | c.2536G>A p.E846K | Missense Mutation (SNP) | VAF 30/47 reads (64%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.999); catalogued as rs780851806, COSV59147668; called by muse, mutect2, varscan2
- ATP13A5 | c.2746C>T p.Q916* | Nonsense Mutation (SNP) | VAF 35/137 reads (26%) | catalogued as COSV100665637; called by muse, mutect2, varscan2
- ATP1A3 | c.1750G>A p.D584N (on ENST00000545399 / NM_001256214.2; = p.D571N on NM_152296.5) | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as rs782694072, COSV100132509, COSV57490342; called by muse, mutect2
- ATP8B4 | c.2080G>A p.D694N | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.841); catalogued as rs1329864798, COSV99463415, COSV99467118; called by muse, varscan2
- AVPR1A | c.799C>T p.Q267* | Nonsense Mutation (SNP) | VAF 43/152 reads (28%) | catalogued as COSV100146898; called by muse, mutect2, varscan2
- BACH2 | c.412G>A p.D138N | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.879); catalogued as COSV100000720; called by muse, mutect2, varscan2
- BAZ1A | c.2606C>T p.S869F | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.85); catalogued as COSV62409577; called by muse, mutect2, varscan2
- BBS9 | c.2012T>C p.V671A (on ENST00000242067 / NM_001348036.1; = p.V631A on NM_014451.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 33/143 reads (23%) | SIFT tolerated (0.91); PolyPhen benign (0.281); catalogued as COSV99629696; called by muse, mutect2, varscan2
- BCL11A | c.373G>A p.E125K | Missense Mutation (SNP) | VAF 22/88 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as COSV59625258; called by muse, mutect2, varscan2
- BCOR | c.3301C>T p.P1101S | Missense Mutation (SNP) | VAF 17/30 reads (57%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV100653197; called by muse, mutect2, varscan2
- BCORL1 | c.550C>T p.P184S | Missense Mutation (SNP) | VAF 29/46 reads (63%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0.098); catalogued as rs1282995868, COSV54390530; called by muse, mutect2, varscan2
- BCORL1 | c.1900C>T p.P634S | Missense Mutation (SNP) | VAF 28/50 reads (56%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as COSV99500681; called by muse, mutect2, varscan2
- BFAR | c.1063C>T p.H355Y | Missense Mutation (SNP) | VAF 29/87 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.813); catalogued as rs890762788, COSV99902415; called by muse, mutect2, varscan2
- BICDL1 | c.922C>T p.Q308* | Nonsense Mutation (SNP) | VAF 22/37 reads (59%) | catalogued as COSV99985937; called by muse, mutect2, varscan2
- BMP4 | c.664C>T p.L222F | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.616); catalogued as COSV99817111; called by muse, mutect2, varscan2
- BMP5 | c.43C>T p.L15F | Missense Mutation (SNP) | VAF 39/150 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.01); catalogued as COSV100896291; called by muse, mutect2, varscan2
- BNIP3 | c.283G>A p.G95S | Missense Mutation (SNP) | VAF 32/103 reads (31%) | SIFT tolerated (0.72); PolyPhen benign (0.003); catalogued as COSV100893283; called by muse, mutect2, varscan2
- BPNT1 | c.553G>C p.V185L | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV100435595, COSV100435811; called by muse, mutect2, varscan2
- BRINP1 | c.58G>A p.V20M | Missense Mutation (SNP) | VAF 33/88 reads (38%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.56); catalogued as COSV99776688; called by muse, mutect2, varscan2
- BRINP3 | c.1918G>A p.G640S | Missense Mutation (SNP) | VAF 32/182 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.039); catalogued as rs1289601897, COSV100819326; called by muse, mutect2, varscan2
- BRINP3 | c.1041G>A p.M347I | Missense Mutation (SNP) | VAF 19/112 reads (17%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as COSV66526550; called by muse, mutect2, varscan2
- BTC | c.301G>A p.G101R | Missense Mutation (SNP) | VAF 40/149 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101201550; called by muse, mutect2, varscan2
- C10orf120 | c.386A>G p.H129R | Missense Mutation (SNP) | VAF 53/174 reads (30%) | SIFT tolerated (0.34); PolyPhen benign (0.164); catalogued as COSV100271741; called by muse, mutect2, varscan2
- C12orf40 | c.1747G>A p.D583N | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1339241267, COSV100210773, COSV61129811; called by muse, mutect2, varscan2
- C14orf28 | c.428T>G p.L143R | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV100290338; called by muse, mutect2, varscan2
- C16orf90 | c.101C>T p.P34L (on ENST00000399645 / NM_001353385.2; = p.P25L on NM_001080524.2) | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.011); catalogued as COSV101290972; called by muse, mutect2, varscan2
- C18orf21 | c.75C>T p.L25= | Splice Region (SNP) | VAF 8/35 reads (23%) | catalogued as COSV52450166; called by muse, mutect2, varscan2
- C1QTNF9B | c.140G>A p.G47E | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs764649898, COSV65944559; called by muse, mutect2, varscan2
- C1orf116 | c.691C>T p.H231Y | Missense Mutation (SNP) | VAF 16/122 reads (13%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.731); catalogued as COSV100848008; called by muse, mutect2, varscan2
- C2CD3 | c.4985C>T p.P1662L | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.633); catalogued as COSV100487292; called by muse, mutect2, varscan2
- C2orf16 | c.548C>T p.P183L | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.174); catalogued as COSV101284411; called by muse, mutect2, varscan2
- C5orf51 | c.662G>A p.G221E | Missense Mutation (SNP) | VAF 34/93 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV101069046; called by muse, mutect2, varscan2
- C6 | c.2155C>T p.Q719* | Nonsense Mutation (SNP) | VAF 13/58 reads (22%) | catalogued as COSV54715083, COSV99667057; called by muse, mutect2, varscan2
- C6 | c.481G>A p.E161K | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.742); catalogued as COSV54718413; called by muse, mutect2, varscan2
- C7 | c.731A>T p.K244I | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.133); catalogued as rs199558578, COSV100496475; called by muse, mutect2, varscan2
- C8A | c.169A>T p.K57* | Nonsense Mutation (SNP) | VAF 14/77 reads (18%) | catalogued as COSV100776656; called by muse, mutect2, varscan2
- C9orf135 | c.440G>A p.W147* | Nonsense Mutation (SNP) | VAF 23/75 reads (31%) | catalogued as COSV101019913; called by muse, mutect2, varscan2
- CACNA1E | c.5089G>A p.D1697N | Missense Mutation (SNP) | VAF 20/132 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.149); catalogued as rs768500940, COSV62387967, COSV62424409; called by muse, mutect2
- CACNA1G | c.1717C>T p.P573S | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as COSV100662403; called by muse, mutect2
- CACNA1H | c.4061C>T p.S1354F | Missense Mutation (SNP) | VAF 20/41 reads (49%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as rs754994425, COSV100673375; called by muse, mutect2, varscan2
- CACNA1H | c.6706G>A p.E2236K | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.111); catalogued as COSV99327037; called by muse, mutect2
- CACNA1I | c.895G>A p.D299N | Missense Mutation (SNP) | VAF 42/75 reads (56%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.774); catalogued as COSV60819413; called by muse, mutect2, varscan2
- CACNA1S | c.4964C>T p.P1655L | Missense Mutation (SNP) | VAF 41/92 reads (45%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.033); catalogued as COSV100755309; called by muse, mutect2, varscan2
- CACNA1S | c.1005G>A p.G335= | Splice Region (SNP) | VAF 20/55 reads (36%) | catalogued as COSV62945938; called by muse, mutect2, varscan2
- CACNG3 | c.838C>T p.L280F | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.15); catalogued as rs1305652725, COSV50064569; called by muse, mutect2, varscan2
- CADPS | c.2300G>A p.G767E | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99337315; called by muse, mutect2
- CALHM6 | c.782C>T p.S261L | Missense Mutation (SNP) | VAF 36/126 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV63991832; called by muse, mutect2, varscan2
- CAPN10 | c.1543G>A p.G515R | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.091); catalogued as COSV99550514, COSV99550521; called by muse, varscan2
- CAPN15 | c.3056C>T p.T1019I | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV99562769; called by muse, mutect2, varscan2
- CAPZA3 | c.205C>T p.P69S | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT tolerated (0.8); PolyPhen benign (0.017); catalogued as COSV56854582; called by muse, mutect2, varscan2
- CARD11 | c.778C>T p.R260W | Missense Mutation (SNP) | VAF 36/132 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV67797093, COSV67802579; called by muse, mutect2, varscan2
- CASR | c.1078C>T p.L360F | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT tolerated (0.58); PolyPhen benign (0.07); catalogued as rs751813138, COSV99949385; called by muse, mutect2, varscan2
- CATSPERE | c.944G>A p.R315K | Missense Mutation (SNP) | VAF 31/93 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100835331; called by muse, mutect2, varscan2
- CBLB | c.986A>T p.Y329F | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); catalogued as COSV99913513, COSV99914173; called by muse, mutect2, varscan2
- CBLN1 | c.466G>A p.G156R | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as rs1188699698, COSV99535649; called by muse, mutect2, varscan2
- CCDC158 | c.3058C>T p.P1020S | Missense Mutation (SNP) | VAF 31/107 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1478138967, COSV101187352; called by muse, mutect2, varscan2
- CCDC17 | c.1289G>A p.R430K | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.41); PolyPhen benign (0.027); catalogued as rs1377378753, COSV100601975; called by muse, varscan2
- CCDC178 | c.319G>A p.E107K | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100284605, COSV55777457, COSV55796096; called by muse, mutect2, varscan2
- CCDC191 | c.1430C>T p.P477L | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT tolerated (0.64); PolyPhen benign (0.003); catalogued as COSV99878689; called by muse, mutect2, varscan2
- CCDC88C | c.4586C>T p.P1529L | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as COSV100485039; called by muse, mutect2, varscan2
- CCL7 | c.179C>T p.P60L | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.737); catalogued as COSV52337926; called by muse, mutect2, varscan2
- CCNE1 | c.728C>T p.P243L | Missense Mutation (SNP) | VAF 36/155 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99388601; called by muse, mutect2, varscan2
- CCR2 | c.779A>T p.N260I | Missense Mutation (SNP) | VAF 31/128 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as COSV99432722; called by muse, mutect2, varscan2
- CD109 | c.1342C>T p.L448F | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.364); catalogued as COSV99754406; called by muse, mutect2, varscan2
- CD163 | c.1744G>A p.E582K | Missense Mutation (SNP) | VAF 31/82 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.169); catalogued as COSV100776082, COSV63130696; called by muse, mutect2, varscan2
- CD180 | c.1037C>T p.S346F | Missense Mutation (SNP) | VAF 40/129 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV99842359; called by muse, mutect2, varscan2
- CD1A | c.274A>T p.I92F | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT tolerated (0.34); PolyPhen benign (0.009); catalogued as COSV99192579; called by muse, mutect2, varscan2
- CD226 | c.10C>T p.P4S | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.045); catalogued as COSV99711470; called by muse, mutect2, varscan2
- CD300E | c.16G>A p.A6T | Missense Mutation (SNP) | VAF 28/103 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.029); catalogued as COSV100151494; called by muse, mutect2, varscan2
- CDC20B | c.886G>A p.E296K | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.977); catalogued as COSV99697314; called by muse, mutect2, varscan2
- CDC25B | c.714T>A p.S238R (on ENST00000245960 / NM_021873.3; = p.S224R on NM_004358.4) | Missense Mutation (SNP) | VAF 23/88 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.568); catalogued as COSV99848315; called by muse, mutect2, varscan2
- CDC37L1 | c.486T>G p.Y162* | Nonsense Mutation (SNP) | VAF 5/29 reads (17%) | catalogued as COSV101116645; called by muse, mutect2
- CDC40 | c.1213A>G p.I405V | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT tolerated (0.6); PolyPhen benign (0.005); catalogued as rs769358205, COSV100309546; called by muse, mutect2, varscan2
- CDH10 | c.1210G>A p.G404S | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV52596978; called by muse, mutect2, varscan2
- CDH18 | c.71G>A p.G24E | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT tolerated (0.25); PolyPhen benign (0.021); catalogued as COSV56924149, COSV56947682; called by muse, mutect2, varscan2
- CDH20 | c.79G>A p.D27N | Missense Mutation (SNP) | VAF 29/101 reads (29%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV53016461; called by muse, mutect2, varscan2
- CDH23 | c.3149C>T p.A1050V | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.301); catalogued as COSV54922974, COSV54928146; called by muse, mutect2, varscan2
- CDH6 | c.1633A>T p.N545Y | Missense Mutation (SNP) | VAF 26/79 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99420602; called by muse, mutect2, varscan2
- CDH7 | c.719G>A p.G240E | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100543087; called by muse, mutect2, varscan2
- CDH7 | c.1069C>T p.P357S | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.998); catalogued as COSV59888974; called by muse, mutect2, varscan2
- CDH8 | c.701G>A p.R234K | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100182006; called by muse, mutect2, varscan2
- CDH8 | c.310G>A p.G104R | Missense Mutation (SNP) | VAF 21/85 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100183837; called by muse, mutect2, varscan2
- CDH9 | c.2033G>A p.R678K | Missense Mutation (SNP) | VAF 27/87 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV50251191; called by muse, mutect2, varscan2
- CEACAM20 | c.37G>A p.G13R | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as COSV100387013; called by muse, mutect2, varscan2
- CEACAM4 | c.49G>A p.G17R | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.768); catalogued as COSV99701181; called by muse, mutect2, varscan2
- CELA2A | c.85G>T p.V29L | Missense Mutation (SNP) | VAF 29/58 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.217); catalogued as COSV100657604; called by muse, mutect2, varscan2
- CELSR1 | c.2596G>A p.D866N | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99419746; called by muse, mutect2, varscan2
- CENPE | c.7511G>A p.R2504K | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV99478911; called by muse, mutect2, varscan2
- CEP112 | c.1737G>A p.K579= | Splice Region (SNP) | VAF 21/132 reads (16%) | catalogued as COSV101211093; called by muse, mutect2, varscan2
- CEP128 | c.1627C>T p.R543* | Nonsense Mutation (SNP) | VAF 14/40 reads (35%) | catalogued as rs780056351, COSV99825760; called by muse, mutect2, varscan2
- CEP72 | c.1745A>G p.Q582R | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV99375241; called by muse, mutect2, varscan2
- CEP97 | c.2081C>T p.S694L | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.023); catalogued as COSV59126391; called by muse, mutect2, varscan2
- CERKL | c.1565C>T p.P522L (on ENST00000339098 / NM_001030311.2; = p.P496L on NM_201548.5) | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.062); catalogued as COSV100184096; called by muse, mutect2, varscan2
- CFAP43 | c.4963A>T p.R1655* | Nonsense Mutation (SNP) | VAF 15/48 reads (31%) | catalogued as COSV100312418; called by muse, mutect2, varscan2
- CFAP58 | c.563G>A p.R188Q | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as rs746292556, COSV57211513; called by muse, mutect2, varscan2
- CFAP58 | c.1058C>T p.T353I | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as rs1420549634, COSV100459085, COSV57212465; called by muse, mutect2, varscan2
- CFC1 | c.188G>A p.G63E | Missense Mutation (SNP) | VAF 16/123 reads (13%) | SIFT tolerated (0.89); PolyPhen benign (0.003); catalogued as COSV52090269, COSV99383512; called by muse, mutect2, varscan2
- CFH | c.557G>A p.G186E | Missense Mutation (SNP) | VAF 24/99 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100661615; called by muse, mutect2, varscan2
- CHD5 | c.3907G>A p.E1303K | Missense Mutation (SNP) | VAF 25/42 reads (60%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as COSV99314768; called by muse, mutect2, varscan2
- CHD8 | c.1339G>A p.E447K (on ENST00000646647 / NM_001170629.2; = p.E168K on NM_020920.4) | Missense Mutation (SNP) | VAF 35/112 reads (31%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0.007); catalogued as COSV101303202; called by muse, mutect2, varscan2
- CHDH | c.1198T>C p.F400L | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV100179854; called by muse, mutect2, varscan2
- CHERP | c.1163C>T p.S388F | Missense Mutation (SNP) | VAF 29/98 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.367); catalogued as COSV99550476; called by muse, mutect2, varscan2
- CHIA | c.630G>A p.M210I (on ENST00000343320; = p.M102I on NM_021797.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100588809; called by muse, mutect2, varscan2
- CHRM2 | c.49C>T p.P17S | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT tolerated (0.1); PolyPhen probably damaging (1); catalogued as COSV57769642; called by muse, mutect2, varscan2
- CHRM2 | c.1310C>T p.P437L | Missense Mutation (SNP) | VAF 34/126 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57783812, COSV57787676; called by muse, mutect2, varscan2
- CHRM5 | c.134T>A p.I45N | Missense Mutation (SNP) | VAF 19/84 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.295); catalogued as COSV101272034; called by muse, mutect2, varscan2
- CHST4 | c.666G>A p.M222I | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0.14); catalogued as COSV100632931; called by muse, mutect2, varscan2
- CILP2 | c.613G>A p.E205K | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV99365108; called by muse, mutect2, varscan2
- CLCA2 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 13/70 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.971); catalogued as COSV100991686; called by muse, mutect2, varscan2
- CLDN11 | c.592T>G p.S198A | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT tolerated (0.55); PolyPhen benign (0.007); catalogued as COSV99291126; called by muse, mutect2, varscan2
- CMTM1 | c.493C>T p.P165S (on ENST00000457188 / NM_181269.3; = p.P282S on NM_052999.4) | Missense Mutation (SNP) | VAF 25/83 reads (30%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); catalogued as COSV99216566; called by muse, mutect2, varscan2
- CMTR1 | c.1346T>C p.L449P | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.601); catalogued as COSV100990922; called by muse, mutect2, varscan2
- CMTR2 | c.376C>T p.P126S | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.153); catalogued as COSV57604655; called by muse, mutect2, varscan2
- CNGA2 | c.1030C>T p.P344S | Missense Mutation (SNP) | VAF 39/66 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100323905; called by muse, mutect2, varscan2
- CNTN2 | c.215+1G>A p.X72_splice | Splice Site (SNP) | VAF 3/15 reads (20%) | catalogued as COSV100085406; called by muse, mutect2
- CNTN5 | c.1051C>T p.Q351* | Nonsense Mutation (SNP) | VAF 24/75 reads (32%) | catalogued as COSV99680543; called by muse, mutect2, varscan2
- COL11A1 | c.5006G>A p.G1669E | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.669); catalogued as COSV100617896; called by muse, mutect2, varscan2
- COL11A2 | c.2119C>T p.P707S (on ENST00000341947 / NM_080680.3; = p.P600S on NM_080679.2) | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as COSV100554444; called by muse, mutect2, varscan2
- COL11A2 | c.1210G>C p.E404Q (on ENST00000341947 / NM_080680.3; = p.E297Q on NM_080679.2) | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.975); catalogued as COSV100554445; called by muse, mutect2, varscan2
- COL3A1 | c.1960G>A p.G654R | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.142); catalogued as COSV100483091, COSV100483638; called by muse, mutect2, varscan2
- COL4A4 | c.1897G>A p.G633R | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1445668955, COSV100306531, COSV100307557; called by muse, mutect2
- COL4A5 | c.1126C>T p.P376S | Missense Mutation (SNP) | VAF 37/56 reads (66%) | SIFT deleterious (0.01); PolyPhen benign (0.168); catalogued as COSV100087433, COSV60374442; called by muse, mutect2, varscan2
- COL4A5 | c.2651G>A p.G884E | Missense Mutation (SNP) | VAF 13/18 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100089467; called by muse, mutect2, varscan2
- COL5A3 | c.2333C>T p.P778L | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.69); PolyPhen benign (0.021); catalogued as rs1424377071, COSV99319653; called by muse, mutect2
- COL5A3 | c.1587+1G>A p.X529_splice | Splice Site (SNP) | VAF 9/35 reads (26%) | catalogued as COSV99319654; called by muse, mutect2, varscan2
- COL6A6 | c.2918G>A p.G973E | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated (0.71); PolyPhen benign (0.047); catalogued as COSV100650830, COSV62024971; called by muse, mutect2, varscan2
- COLGALT1 | c.1429C>T p.P477S | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.119); catalogued as COSV99395247; called by muse, mutect2, varscan2
- COLQ | c.274C>T p.P92S | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT tolerated (0.48); PolyPhen benign (0.001); catalogued as COSV67525011; called by muse, varscan2
- COQ9 | c.734C>T p.A245V | Missense Mutation (SNP) | VAF 24/94 reads (26%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.732); catalogued as COSV99345968; called by muse, mutect2, varscan2
- CORIN | c.784G>A p.E262K | Missense Mutation (SNP) | VAF 25/98 reads (26%) | SIFT tolerated (0.48); PolyPhen benign (0.205); catalogued as rs866164544, COSV56688788; called by muse, mutect2, varscan2
- CP | c.1774C>T p.L592F | Missense Mutation (SNP) | VAF 29/91 reads (32%) | SIFT tolerated (0.05); PolyPhen benign (0.018); catalogued as rs200226362, COSV52835593; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CPA5 | c.193C>T p.Q65* | Nonsense Mutation (SNP) | VAF 23/77 reads (30%) | catalogued as COSV100812444; called by muse, mutect2, varscan2
- CPAMD8 | c.4278G>A p.M1426I (on ENST00000651564; = p.M1379I on NM_015692.5) | Missense Mutation (SNP) | VAF 19/77 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.094); catalogued as COSV101488569; called by muse, mutect2, varscan2
- CPAMD8 | c.3478C>T p.P1160S (on ENST00000651564; = p.P1113S on NM_015692.5) | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV101488571; called by muse, mutect2, varscan2
- CPD | c.1583C>T p.S528F | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99853211; called by muse, mutect2, varscan2
- CPEB2 | c.2147C>T p.P716L | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.155); catalogued as COSV99470597; called by muse, mutect2, varscan2
- CPNE7 | c.814G>A p.E272K | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV52014494; called by muse, mutect2, varscan2
- CPXM1 | c.1151G>A p.G384E | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs755133941, COSV101013822; called by muse, mutect2, varscan2
- CPXM2 | c.1612G>A p.E538K | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.1); catalogued as COSV53855569; called by muse, mutect2, varscan2
- CPXM2 | c.798G>A p.M266I | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated (0.16); PolyPhen benign (0.017); catalogued as COSV53863647; called by muse, mutect2, varscan2
- CPXM2 | c.497G>A p.G166E | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs869025241, COSV99583170; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CR2 | c.1423G>A p.G475R | Missense Mutation (SNP) | VAF 44/90 reads (49%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.466); catalogued as COSV65508303; called by muse, mutect2, varscan2
- CR2 | c.1552G>A p.E518K | Missense Mutation (SNP) | VAF 34/79 reads (43%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.692); catalogued as COSV100889696; called by muse, mutect2, varscan2
- CRB1 | c.3737G>A p.G1246E | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV66332352; called by muse, mutect2, varscan2
- CRTC1 | c.438G>A p.W146* | Nonsense Mutation (SNP) | VAF 13/39 reads (33%) | catalogued as COSV100119552; called by muse, mutect2, varscan2
- CRTC2 | c.830A>G p.D277G | Missense Mutation (SNP) | VAF 37/76 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100339308; called by muse, mutect2, varscan2
- CRYBB2 | c.269G>A p.R90K | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.017); catalogued as COSV101236766; called by muse, mutect2, varscan2
- CSMD1 | c.5930G>A p.G1977E (on ENST00000520002; = p.G1976E on NM_033225.6) | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100152929; called by muse, mutect2, varscan2
- CSMD1 | c.3940G>A p.G1314R (on ENST00000520002; = p.G1313R on NM_033225.6) | Missense Mutation (SNP) | VAF 33/89 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV100152931; called by muse, mutect2, varscan2
- CSMD1 | c.2810G>A p.G937E (on ENST00000520002; = p.G936E on NM_033225.6) | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100152348, COSV59358374; called by muse, mutect2, varscan2
- CSMD2 | c.8423G>A p.G2808E | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV53977100; called by muse, mutect2, varscan2
- CSMD2 | c.3493G>A p.G1165R | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1233185953, COSV99594432; called by muse, mutect2, varscan2
- CSN1S1 | c.478C>T p.P160S | Missense Mutation (SNP) | VAF 35/147 reads (24%) | SIFT tolerated (0.54); PolyPhen benign (0.025); catalogued as COSV55890657; called by muse, varscan2
- CSNK1A1L | c.28G>A p.E10K | Missense Mutation (SNP) | VAF 33/94 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.075); catalogued as rs1481438221, COSV65789271; called by muse, mutect2, varscan2
- CST9L | c.151G>A p.V51M | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.787); catalogued as COSV100980907; called by muse, mutect2, varscan2
- CTAGE1 | c.2189C>T p.P730L | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated (0.24); PolyPhen benign (0.197); catalogued as COSV66944293; called by muse, mutect2
- CUEDC2 | c.293C>T p.P98L | Missense Mutation (SNP) | VAF 31/112 reads (28%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.902); catalogued as rs778210426, COSV56523974, COSV99827968; called by muse, mutect2, varscan2
- CUEDC2 | c.292C>T p.P98S | Missense Mutation (SNP) | VAF 32/114 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.852); catalogued as COSV99827971; called by muse, mutect2, varscan2
- CWH43 | c.1894G>A p.E632K | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.107); catalogued as COSV56935687; called by muse, mutect2, varscan2
- CYFIP2 | c.433C>T p.H145Y | Missense Mutation (SNP) | VAF 20/23 reads (87%) | SIFT deleterious (0); PolyPhen possibly damaging (0.478); catalogued as COSV100557671; called by muse, mutect2, varscan2
- CYP19A1 | c.1447G>A p.E483K | Missense Mutation (SNP) | VAF 24/93 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.195); catalogued as COSV53062773; called by muse, mutect2, varscan2
- CYP2C8 | c.53C>T p.S18L | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as COSV64877768; called by muse, mutect2, varscan2
- CYP2C9 | c.1210C>T p.P404S | Missense Mutation (SNP) | VAF 28/106 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV53253404, COSV99583126; called by muse, mutect2, varscan2
- CYP3A4 | c.1532G>A p.G511E (on ENST00000336411; = p.G480E on NM_017460.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT tolerated (0.36); PolyPhen benign (0.001); catalogued as rs1287224156, COSV100315850; called by muse, mutect2, varscan2
- CYP4A11 | c.829G>A p.E277K | Missense Mutation (SNP) | VAF 39/111 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.11); catalogued as COSV100152597; called by muse, mutect2, varscan2
- CYP4F2 | c.432G>A p.W144* | Nonsense Mutation (SNP) | VAF 18/64 reads (28%) | catalogued as rs774408246, COSV50001849, COSV99171133; called by muse, mutect2, varscan2
- CYP4Z1 | c.113G>A p.W38* | Nonsense Mutation (SNP) | VAF 23/60 reads (38%) | catalogued as COSV100497898, COSV100497918; called by muse, mutect2, varscan2
- CYP8B1 | c.1252G>A p.D418N | Missense Mutation (SNP) | VAF 36/132 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.114); catalogued as COSV100296271; called by muse, mutect2, varscan2
- DAB1 | c.235G>A p.G79R | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.795); catalogued as COSV100139112, COSV100140709; called by muse, mutect2, varscan2
- DAOA | c.183G>A p.W61* | Nonsense Mutation (SNP) | VAF 12/50 reads (24%) | catalogued as rs1461859694, COSV100298880; called by mutect2, varscan2
- DAPK2 | c.614G>A p.G205D | Missense Mutation (SNP) | VAF 23/83 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99977706; called by muse, mutect2, varscan2
- DCANP1 | c.136C>T p.P46S | Missense Mutation (SNP) | VAF 18/22 reads (82%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.799); catalogued as COSV101538274; called by muse, mutect2, varscan2
- DCC | c.3022C>T p.Q1008* | Nonsense Mutation (SNP) | VAF 31/98 reads (32%) | catalogued as COSV100502495; called by muse, mutect2, varscan2
- DCD | c.176G>T p.R59M | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated, low confidence (0.13); PolyPhen possibly damaging (0.85); catalogued as COSV53201360, COSV99514082; called by muse, mutect2, varscan2
- DCLK2 | c.1579C>T p.P527S | Missense Mutation (SNP) | VAF 31/96 reads (32%) | SIFT tolerated (0.57); PolyPhen benign (0.014); catalogued as COSV56207201; called by muse, mutect2, varscan2
- DCLRE1A | c.716C>T p.P239L | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT tolerated (0.19); PolyPhen benign (0.036); catalogued as rs990104070, COSV100800469; called by muse, mutect2, varscan2
- DCLRE1A | c.715C>T p.P239S | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as rs147324917; called by muse, mutect2, varscan2
- DCSTAMP | c.865G>A p.E289K | Missense Mutation (SNP) | VAF 37/107 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); catalogued as COSV52576279, COSV52578645; called by muse, mutect2, varscan2
- DGKQ | c.2153T>G p.L718R | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99298177; called by muse, mutect2, varscan2
- DHX30 | c.31C>T p.R11W | Missense Mutation (SNP) | VAF 46/150 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.973); catalogued as rs1431016354, COSV100819901; called by muse, mutect2, varscan2
- DHX36 | c.1837C>T p.H613Y | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.566); catalogued as COSV100273907; called by muse, mutect2, varscan2
- DISC1 | c.1565C>T p.A522V | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as COSV99698471; called by muse, mutect2, varscan2
- DMBT1 | c.5294C>T p.S1765F (on ENST00000338354 / NM_001377530.1; = p.S1008F on NM_004406.3) | Missense Mutation (SNP) | VAF 72/248 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV100353964; called by muse, varscan2
- DMBT1 | c.5320G>A p.G1774R (on ENST00000338354 / NM_001377530.1; = p.G1017R on NM_004406.3) | Missense Mutation (SNP) | VAF 84/286 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100353968; called by muse, varscan2
- DMBX1 | c.446G>A p.G149E | Missense Mutation (SNP) | VAF 18/85 reads (21%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as rs1212713760, COSV100760880; called by muse, mutect2, varscan2
- DMP1 | c.539G>A p.G180E | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.863); catalogued as rs988518101, COSV56819332; called by muse, mutect2, varscan2
- DNAAF5 | c.1939C>T p.P647S | Missense Mutation (SNP) | VAF 25/97 reads (26%) | SIFT tolerated (0.57); PolyPhen benign (0.003); catalogued as COSV52415492; called by muse, mutect2, varscan2
- DNAH12 | c.1073C>T p.A358V | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT tolerated (0.58); PolyPhen benign (0.024); catalogued as COSV100244746; called by muse, mutect2, varscan2
- DNAH2 | c.8770G>A p.E2924K | Missense Mutation (SNP) | VAF 48/132 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.635); catalogued as COSV101209555; called by muse, mutect2, varscan2
- DNAH5 | c.10859G>A p.R3620Q | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs547014532, COSV54205387, COSV54209411; called by muse, mutect2, varscan2
- DNAH5 | c.200G>A p.R67K | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT tolerated (0.91); PolyPhen benign (0.001); catalogued as COSV54220751, COSV54250140; called by muse, mutect2, varscan2
- DNAH7 | c.5771G>A p.G1924E | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1318626642, COSV100413722; called by muse, mutect2, varscan2
- DNAH7 | c.2302C>T p.R768C | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); catalogued as rs192646926; called by muse, mutect2, varscan2
- DNAH8 | c.2730G>T p.M910I | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as COSV100546917, COSV59428322; called by muse, mutect2, varscan2
- DNAH8 | c.5678C>T p.S1893F | Missense Mutation (SNP) | VAF 31/109 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100544932, COSV99046886; called by muse, mutect2, varscan2
- DNAH8 | c.7649G>A p.G2550E | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59422807; called by muse, mutect2, varscan2
- DNAH9 | c.9359G>A p.R3120K | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV99307703; called by muse, mutect2, varscan2
- DOCK10 | c.4046C>T p.S1349L | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs374472028; called by muse, mutect2, varscan2
- DOCK3 | c.3380G>A p.R1127K | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.928); catalogued as rs1156444497, COSV99809708; called by muse, mutect2, varscan2
- DOCK9 | c.4985C>T p.P1662L (on ENST00000376460 / NM_001366676.2; = p.P1663L on NM_015296.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); catalogued as COSV100240763; called by muse, mutect2, varscan2
- DOCK9 | c.4984C>T p.P1662S (on ENST00000376460 / NM_001366676.2; = p.P1663S on NM_015296.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated, low confidence (0.97); PolyPhen benign (0.001); catalogued as COSV59627238; called by muse, mutect2, varscan2
- DPP6 | c.1663G>A p.E555K (on ENST00000377770 / NM_001364500.2; = p.E493K on NM_001936.5) | Missense Mutation (SNP) | VAF 30/76 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.135); catalogued as rs1484002939, COSV100127722; called by muse, mutect2, varscan2
- DPPA2 | c.584G>A p.R195K | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT tolerated (0.29); PolyPhen benign (0.114); catalogued as rs755524086, COSV101524793; called by muse, mutect2, varscan2
- DPPA5 | c.134C>T p.P45L | Missense Mutation (SNP) | VAF 24/103 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.043); catalogued as COSV100951518, COSV100951533; called by muse, mutect2, varscan2
- DPY19L2 | c.1645C>T p.L549F | Missense Mutation (SNP) | VAF 21/37 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV61043618; called by muse, varscan2
- DPY19L2 | c.1643C>T p.A548V | Missense Mutation (SNP) | VAF 19/37 reads (51%) | SIFT tolerated (0.8); PolyPhen benign (0.006); catalogued as rs1318541208, COSV100193961; called by muse, varscan2
- DPYD | c.1784C>T p.T595I | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100929326; called by muse, mutect2, varscan2
- DQX1 | c.1715G>A p.R572Q | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.075); catalogued as rs753263732, COSV52045499; called by muse, mutect2, varscan2
- DSC3 | c.529G>A p.G177R | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100844703; called by muse, mutect2, varscan2
- DSCAM | c.5721G>A p.M1907I | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT tolerated, low confidence (0.12); PolyPhen possibly damaging (0.838); catalogued as COSV68029944; called by muse, mutect2, varscan2
- DSCAM | c.5324C>T p.A1775V | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT tolerated (0.64); PolyPhen benign (0.001); catalogued as COSV101261385; called by muse, mutect2, varscan2
- DSCAM | c.3457G>A p.D1153N | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.756); catalogued as COSV101261386; called by muse, mutect2, varscan2
- DSG1 | c.604G>A p.E202K | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.904); catalogued as COSV99936464; called by muse, mutect2, varscan2
- DSG1 | c.790G>A p.D264N | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99936466; called by muse, mutect2, varscan2
- DSG2 | c.836G>A p.G279E | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.974); catalogued as COSV99853491; called by muse, mutect2, varscan2
- DSG4 | c.866G>A p.R289Q | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs758840509, COSV57397410; called by muse, mutect2, varscan2
- DSG4 | c.3092G>A p.R1031Q | Missense Mutation (SNP) | VAF 18/90 reads (20%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs372042028; called by muse, mutect2
- DSP | c.1369A>C p.S457R | Missense Mutation (SNP) | VAF 22/100 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.017); catalogued as COSV101131674; called by muse, mutect2, varscan2
- DSP | c.8492C>T p.S2831L | Missense Mutation (SNP) | VAF 30/122 reads (25%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.025); catalogued as rs761243454, COSV100673051; called by muse, mutect2, varscan2
- DVL2 | c.1355C>T p.A452V | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1474129740, COSV99138796; called by muse, mutect2, varscan2
- DYNC1H1 | c.6212C>T p.P2071L | Missense Mutation (SNP) | VAF 26/122 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs757634780, COSV100795306; called by muse, mutect2, varscan2
- DYRK1A | c.407A>G p.Y136C | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.545); catalogued as rs750128893, COSV100118219; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DZIP1 | c.2005C>T p.P669S (on ENST00000347108; = p.P650S on NM_014934.5) | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT tolerated (0.6); PolyPhen benign (0.007); catalogued as rs761770434, COSV61271752; called by muse, mutect2, varscan2
- ECSIT | c.100C>T p.P34S | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99369217; called by muse, mutect2, varscan2
- EEF1AKMT1 | c.631G>A p.D211N | Missense Mutation (SNP) | VAF 37/158 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.018); catalogued as COSV101236950; called by muse, mutect2, varscan2
- EEF1G | c.381C>T p.A127= | Splice Region (SNP) | VAF 16/56 reads (29%) | catalogued as COSV100240625; called by muse, mutect2, varscan2
- EFCAB12 | c.195G>T p.K65N | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV100394473, COSV100394657; called by muse, mutect2, varscan2
- EFCAB2 | c.640C>T p.P214S (on ENST00000366522; = p.P78S on NM_032328.3) | Missense Mutation (SNP) | VAF 34/115 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.981); catalogued as COSV63655585; called by muse, mutect2, varscan2
- EFCAB6 | c.1285C>T p.R429* | Nonsense Mutation (SNP) | VAF 16/67 reads (24%) | catalogued as rs772599532, COSV53060948; called by muse, mutect2, varscan2
- EFCAB6 | c.385C>T p.L129F | Missense Mutation (SNP) | VAF 32/113 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.851); catalogued as COSV99414250; called by muse, mutect2, varscan2
- EHMT1 | c.2125C>T p.P709S | Missense Mutation (SNP) | VAF 26/97 reads (27%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs1417694539, COSV58373089; called by muse, mutect2, varscan2
- EIF4G1 | c.4196C>T p.A1399V (on ENST00000346169 / NM_198241.3; = p.A1204V on NM_004953.5) | Missense Mutation (SNP) | VAF 24/162 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.009); catalogued as COSV100072237; called by muse, mutect2, varscan2
- ELOVL3 | c.233G>A p.S78N | Missense Mutation (SNP) | VAF 24/77 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.826); catalogued as COSV100892833; called by muse, mutect2, varscan2
- EML5 | c.3946C>T p.R1316C | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs763841931, COSV61348097; called by muse, mutect2
- EPB42 | c.1102G>A p.V368I (on ENST00000441366 / NM_001114134.2; = p.V398I on NM_000119.3) | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.201); catalogued as rs1333626443, COSV100282110; called by muse, mutect2, varscan2
- EPHA6 | c.2486G>A p.G829E (on ENST00000389672 / NM_001080448.3; = p.G221E on NM_173655.4) | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT tolerated, low confidence (0.14); PolyPhen possibly damaging (0.597); catalogued as rs1471269109, COSV67587762; called by muse, mutect2, varscan2
- EPHA7 | c.1975G>A p.D659N | Missense Mutation (SNP) | VAF 20/96 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.116); catalogued as COSV65181898; called by muse, mutect2, varscan2
- EPPIN | c.282G>A p.W94* | Nonsense Mutation (SNP) | VAF 24/87 reads (28%) | catalogued as rs751896217, COSV60549233; called by muse, mutect2, varscan2
- EPPK1 | c.5249C>T p.P1750L | Missense Mutation (SNP) | VAF 17/96 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV101599941; called by muse, mutect2, varscan2
- EPS15 | c.1113+1G>T p.X371_splice | Splice Site (SNP) | VAF 7/28 reads (25%) | catalogued as COSV100869596; called by muse, mutect2, varscan2
- ERAP1 | c.406C>T p.P136S | Missense Mutation (SNP) | VAF 38/81 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.035); catalogued as rs372306542, COSV99701231; called by muse, mutect2, varscan2
- ERC2 | c.1985C>T p.S662F | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as rs765786017, COSV99888847; called by muse, varscan2
- ERC2 | c.1850C>T p.S617F | Missense Mutation (SNP) | VAF 23/87 reads (26%) | SIFT tolerated (0.18); PolyPhen benign (0.378); catalogued as COSV55624356, COSV55662852; called by muse, mutect2, varscan2
- ERC2 | c.428G>A p.R143K | Missense Mutation (SNP) | VAF 34/133 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.018); catalogued as COSV99888850; called by muse, mutect2, varscan2
- ERICH6 | c.1502T>C p.V501A | Missense Mutation (SNP) | VAF 24/89 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV99901929; called by muse, mutect2, varscan2
- ESF1 | c.2368C>T p.L790F | Missense Mutation (SNP) | VAF 28/101 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as rs1240549728, COSV52519694, COSV52520692; called by muse, mutect2, varscan2
- ESYT3 | c.707G>A p.G236E | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs200676435, COSV100004957; called by muse, mutect2, varscan2
- F11 | c.1796G>T p.C599F | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99250905; called by muse, mutect2, varscan2
- F9 | c.590C>T p.P197L | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV99496848; called by muse, mutect2, varscan2
- F9 | c.757G>A p.G253R | Missense Mutation (SNP) | VAF 36/54 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM940572, CM940573, COSV54379181; called by muse, mutect2, varscan2
- FAF1 | c.1115G>A p.R372K | Missense Mutation (SNP) | VAF 23/47 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100876025; called by muse, mutect2, varscan2
- FAM135B | c.1961T>A p.I654N | Missense Mutation (SNP) | VAF 23/84 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV99426859; called by muse, mutect2, varscan2
- FAM135B | c.886C>T p.P296S | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.922); catalogued as COSV99426865; called by muse, mutect2, varscan2
- FAM171A1 | c.2023G>A p.D675N | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs751029098, COSV100968493; called by muse, mutect2, varscan2
- FAM184A | c.1741G>A p.E581K | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.073); catalogued as rs766274838, COSV58851824; called by muse, mutect2, varscan2
- FAM237A | c.70G>A p.G24R | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs1336552931, COSV101405599; called by muse, mutect2
- FAM50B | c.852G>C p.K284N | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100976603; called by muse, mutect2, varscan2
- FAM9C | c.334A>T p.K112* | Nonsense Mutation (SNP) | VAF 22/42 reads (52%) | catalogued as COSV100452879; called by muse, mutect2, varscan2
- FANCD2 | c.2195C>T p.P732L | Missense Mutation (SNP) | VAF 23/84 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs754740540, COSV55033262; called by muse, mutect2, varscan2
- FASTKD1 | c.2374C>T p.P792S | Missense Mutation (SNP) | VAF 26/90 reads (29%) | SIFT tolerated (0.5); PolyPhen benign (0.068); catalogued as COSV99500577; called by muse, mutect2, varscan2
- FAT4 | c.14200G>A p.E4734K | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT deleterious (0.05); PolyPhen benign (0.056); catalogued as COSV58713538; called by muse, mutect2, varscan2
- FBLN2 | c.549T>G p.D183E | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.16); PolyPhen benign (0.031); catalogued as COSV99852515; called by muse, varscan2
- FBP2 | c.782G>A p.G261E | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100942213; called by muse, mutect2, varscan2
- FBXL6 | c.893C>T p.P298L | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.844); catalogued as COSV100096025; called by muse, mutect2, varscan2
- FBXO31 | c.1379C>T p.P460L | Missense Mutation (SNP) | VAF 29/119 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61149506; called by muse, mutect2, varscan2
- FBXW10 | c.1051C>T p.P351S | Missense Mutation (SNP) | VAF 33/81 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100111698; called by muse, mutect2, varscan2
- FCAR | c.485G>A p.G162E | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs775118704, COSV100629172; called by muse, mutect2, varscan2
- FCHO1 | c.2365C>T p.Q789* | Nonsense Mutation (SNP) | VAF 21/77 reads (27%) | catalogued as COSV99406394; called by muse, mutect2, varscan2
- FCRL5 | c.328C>T p.P110S | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.627); catalogued as rs749433298, COSV100709267; called by muse, mutect2, varscan2
- FER1L6 | c.1282G>A p.D428N | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.075); catalogued as COSV67549334; called by muse, mutect2, varscan2
- FER1L6 | c.3388C>T p.P1130S | Missense Mutation (SNP) | VAF 25/152 reads (16%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV67549022, COSV67549785; called by muse, mutect2, varscan2
- FEZ1 | c.1064C>T p.P355L | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV99631053; called by muse, mutect2, varscan2
- FGD2 | c.882G>A p.M294I | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.714); catalogued as COSV99236568; called by muse, mutect2
- FGFRL1 | c.1261G>A p.G421R | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT tolerated (0.33); PolyPhen benign (0.07); catalogued as COSV99294823; called by muse, mutect2
- FLG | c.8207G>A p.G2736E | Missense Mutation (SNP) | VAF 26/219 reads (12%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.841); catalogued as rs775902916, COSV100910313; called by muse, mutect2, varscan2
- FLG2 | c.6296G>A p.G2099E | Missense Mutation (SNP) | VAF 188/464 reads (41%) | SIFT tolerated (0.1); PolyPhen benign (0.063); catalogued as COSV66169652, COSV66174594; called by muse, mutect2, varscan2
- FLG2 | c.1241C>T p.S414F | Missense Mutation (SNP) | VAF 31/143 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV66169308; called by muse, mutect2, varscan2
- FLNC | c.3181G>A p.D1061N | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.966); catalogued as rs1395662654, COSV100368636; called by muse, mutect2, varscan2
- FLRT2 | c.1889C>T p.P630L | Missense Mutation (SNP) | VAF 82/302 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as rs754023658, COSV100420909; called by muse, mutect2, varscan2
- FMN2 | c.2455T>A p.S819T | Missense Mutation (SNP) | VAF 26/87 reads (30%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.003); catalogued as COSV100146918; called by muse, mutect2, varscan2
- FMO3 | c.388G>A p.E130K | Missense Mutation (SNP) | VAF 48/86 reads (56%) | SIFT deleterious (0.04); PolyPhen benign (0.329); catalogued as COSV100882540; called by muse, mutect2, varscan2
- FN1 | c.364G>A p.D122N | Missense Mutation (SNP) | VAF 21/104 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV60549940; called by muse, mutect2
- FNBP1L | c.328A>G p.T110A | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.51); PolyPhen benign (0.109); catalogued as COSV99554946; called by muse, mutect2
- FNBP4 | c.2101C>T p.P701S | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); catalogued as COSV99771939; called by muse, mutect2, varscan2
- FOXA3 | c.593G>A p.G198E | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100141509; called by muse, mutect2, varscan2
- FOXJ2 | c.1633C>T p.P545S | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.289); catalogued as COSV99368898; called by muse, mutect2
- FOXJ2 | c.1634C>T p.P545L | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.436); catalogued as COSV99368900; called by muse, mutect2
- FPR3 | c.242G>A p.R81Q | Missense Mutation (SNP) | VAF 17/89 reads (19%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs757959263, COSV100200850; called by muse, mutect2, varscan2
- FREM2 | c.5293C>T p.R1765C | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.02); catalogued as rs770772406, COSV54826790; called by muse, mutect2, varscan2
- FRMPD1 | c.349G>C p.V117L | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT tolerated (0.34); PolyPhen benign (0.005); catalogued as COSV100733626; called by muse, mutect2, varscan2
- FUT9 | c.28C>T p.R10C | Missense Mutation (SNP) | VAF 39/131 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs376205938; called by muse, mutect2, varscan2
- G3BP1 | c.433C>T p.P145S | Missense Mutation (SNP) | VAF 35/64 reads (55%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.593); catalogued as COSV100664032; called by muse, mutect2, varscan2
- GABRA2 | c.614C>T p.S205L | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.803); catalogued as COSV100734709; called by muse, mutect2, varscan2
- GABRG1 | c.911C>T p.S304L | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as rs568096519, COSV54949731; called by muse, mutect2, varscan2
- GABRQ | c.176T>C p.V59A | Missense Mutation (SNP) | VAF 37/67 reads (55%) | SIFT deleterious (0.05); PolyPhen benign (0.015); catalogued as COSV100941410; called by muse, mutect2, varscan2
- GALNT15 | c.752G>A p.G251E | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.691); catalogued as COSV100327923, COSV100327957; called by muse, mutect2, varscan2
- GALNT5 | c.967G>A p.V323M | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1294961295, COSV99375544; called by muse, mutect2, varscan2
- GALNT7 | c.1489G>A p.E497K | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as COSV99397736; called by muse, mutect2, varscan2
- GBE1 | c.1585G>A p.G529R | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.398); catalogued as COSV101450257; called by muse, mutect2, varscan2
- GCKR | c.890G>A p.R297Q | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT tolerated (0.43); PolyPhen benign (0.012); catalogued as rs760427565, COSV53107187; called by muse, mutect2, varscan2
- GGT1 | c.290C>T p.T97I | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.062); catalogued as rs765580965, COSV99959278; called by muse, mutect2, varscan2
- GHDC | c.746G>A p.R249Q | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.089); catalogued as rs756886734, COSV100054918; called by muse, mutect2, varscan2
- GJA1 | c.568G>A p.D190N | Missense Mutation (SNP) | VAF 18/92 reads (20%) | SIFT tolerated (0.3); PolyPhen benign (0.006); catalogued as COSV99247250; called by muse, mutect2, varscan2
- GKN1 | c.481T>C p.Y161H | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs755914962, COSV100933608, COSV100933628; called by muse, mutect2, varscan2
- GLB1L3 | c.1229C>T p.P410L | Missense Mutation (SNP) | VAF 61/164 reads (37%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.484); catalogued as COSV101345141, COSV101345152; called by muse, mutect2, varscan2
- GLIS3 | c.140C>T p.S47L | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.024); catalogued as rs757118860, COSV67940990; called by muse, mutect2, varscan2
- GLRA3 | c.334C>T p.P112S | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.686); catalogued as COSV56859778; called by muse, mutect2, varscan2
- GNLY | c.118G>A p.E40K | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.043); catalogued as COSV55704312, COSV99809050; called by muse, varscan2
- GOLGB1 | c.1499A>G p.E500G | Missense Mutation (SNP) | VAF 24/98 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.23); catalogued as COSV100511433; called by muse, mutect2, varscan2
- GP2 | c.1537G>A p.G513R (on ENST00000381362 / NM_001007240.3; = p.G510R on NM_001502.4) | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.964); catalogued as COSV56895047; called by muse, mutect2, varscan2
- GPATCH4 | c.652G>A p.E218K | Missense Mutation (SNP) | VAF 20/91 reads (22%) | SIFT tolerated (0.35); PolyPhen benign (0.005); catalogued as COSV100576992; called by muse, mutect2, varscan2
- GPATCH8 | c.545C>T p.S182F | Missense Mutation (SNP) | VAF 24/84 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV100132821; called by muse, mutect2, varscan2
- GPC4 | c.277C>T p.H93Y | Missense Mutation (SNP) | VAF 31/48 reads (65%) | SIFT tolerated (0.06); PolyPhen benign (0.079); catalogued as COSV100895588; called by muse, mutect2, varscan2
- GPC5 | c.218T>G p.M73R | Missense Mutation (SNP) | VAF 30/104 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100995570; called by muse, mutect2, varscan2
- GPER1 | c.944C>G p.S315C | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as rs1311434852, COSV99867326; called by muse, mutect2, varscan2
- GPR155 | c.1781C>T p.S594F | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.569); catalogued as rs149905525, COSV99790190; called by muse, mutect2, varscan2
- GPR61 | c.395C>T p.S132L | Missense Mutation (SNP) | VAF 64/153 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.716); catalogued as rs571875540, COSV68177288; called by muse, mutect2, varscan2
- GPR63 | c.147A>C p.E49D | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0); catalogued as COSV100013544; called by muse, mutect2, varscan2
- GPR84 | c.892G>A p.A298T | Missense Mutation (SNP) | VAF 44/145 reads (30%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as COSV99910126; called by muse, mutect2, varscan2
- GPRC5C | c.587C>T p.P196L (on ENST00000652232; = p.P151L on NM_018653.4) | Missense Mutation (SNP) | VAF 40/128 reads (31%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.646); catalogued as COSV100702984; called by muse, mutect2, varscan2
- GPRC6A | c.1181G>A p.R394K | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT tolerated (0.91); PolyPhen benign (0); catalogued as COSV59951340; called by muse, mutect2, varscan2
- GPRIN3 | c.1628C>T p.P543L | Missense Mutation (SNP) | VAF 21/82 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.011); catalogued as COSV100310955; called by muse, mutect2, varscan2
- GPX5 | c.239C>T p.P80L | Missense Mutation (SNP) | VAF 31/125 reads (25%) | SIFT tolerated (0.8); PolyPhen benign (0.02); catalogued as rs1308994203, COSV69079772; called by muse, mutect2, varscan2
- GREB1 | c.2660G>A p.G887E | Missense Mutation (SNP) | VAF 40/197 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.183); catalogued as rs1003079228, COSV52191138, COSV99302468; called by muse, mutect2, varscan2
- GRHL2 | c.1870G>A p.E624K | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99307714; called by muse, mutect2, varscan2
- GRIN2A | c.2837A>G p.N946S | Missense Mutation (SNP) | VAF 42/147 reads (29%) | SIFT tolerated (0.63); PolyPhen probably damaging (0.989); catalogued as COSV100410813; called by muse, mutect2, varscan2
- GRIN3A | c.574G>A p.G192R | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs755606377, COSV62454820; called by muse, mutect2, varscan2
- GRPR | c.641C>T p.S214F | Missense Mutation (SNP) | VAF 30/47 reads (64%) | SIFT tolerated (0.7); PolyPhen benign (0.161); catalogued as COSV100977692, COSV66669567; called by muse, mutect2, varscan2
- GUCY2C | c.1267G>A p.D423N | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.698); catalogued as COSV99664086; called by muse, mutect2, varscan2
- GXYLT1 | c.1024C>T p.R342* | Nonsense Mutation (SNP) | VAF 22/79 reads (28%) | catalogued as COSV55136974; called by muse, mutect2, varscan2
- GYS2 | c.541G>A p.E181K | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV99680161; called by muse, mutect2, varscan2
- H2BC1 | c.173C>T p.S58L | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as COSV51237068; called by muse, mutect2, varscan2
- HELZ2 | c.2324C>T p.P775L (on ENST00000467148 / NM_001037335.2; = p.P206L on NM_033405.3) | Missense Mutation (SNP) | VAF 26/82 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV100915683; called by muse, mutect2, varscan2
- HELZ2 | c.386C>T p.A129V | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.444); catalogued as COSV100915684; called by muse, mutect2
- HERC2 | c.1330C>G p.Q444E | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT tolerated (0.42); PolyPhen benign (0.017); catalogued as COSV99876340; called by muse, mutect2, varscan2
- HERC5 | c.704C>T p.S235F | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated (0.7); PolyPhen benign (0.245); catalogued as rs756900772, COSV52047196; called by muse, mutect2, varscan2
- HIC2 | c.376C>T p.L126F | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101335624; called by muse, mutect2, varscan2
- HIRA | c.2099C>G p.P700R | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.844); catalogued as COSV99600819; called by muse, mutect2, varscan2
- HIRA | c.1984C>T p.P662S | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT tolerated (0.21); PolyPhen benign (0.057); catalogued as COSV99600822; called by muse, mutect2, varscan2
- HIVEP3 | c.5645C>T p.P1882L | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV99913735; called by muse, mutect2, varscan2
- HK3 | c.2159A>G p.D720G | Missense Mutation (SNP) | VAF 72/143 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99459209; called by muse, mutect2, varscan2
- HKDC1 | c.95C>T p.S32F | Missense Mutation (SNP) | VAF 33/97 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV100664739; called by muse, mutect2, varscan2
- HLA-DMB | c.371C>T p.P124L | Missense Mutation (SNP) | VAF 22/96 reads (23%) | SIFT tolerated (1); PolyPhen probably damaging (1); catalogued as COSV66870735; called by muse, mutect2, varscan2
- HMGCLL1 | c.262G>A p.G88R | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99233076; called by muse, mutect2, varscan2
- HOXD9 | c.716C>T p.S239L | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.026); catalogued as rs751672056, COSV50891747; called by muse, mutect2
- HPS1 | c.223G>A p.E75K | Missense Mutation (SNP) | VAF 25/90 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as COSV100282789; called by muse, mutect2, varscan2
- HRH4 | c.680C>T p.S227L | Missense Mutation (SNP) | VAF 26/94 reads (28%) | SIFT tolerated (0.23); PolyPhen benign (0.02); catalogued as COSV56927964; called by muse, varscan2
- HS3ST4 | c.869C>T p.P290L | Missense Mutation (SNP) | VAF 32/108 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100502650; called by muse, mutect2, varscan2
- HTR3D | c.1067G>A p.G356E (on ENST00000382489 / NM_001163646.2; = p.G181E on NM_182537.3) | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.579); catalogued as COSV100488296; called by muse, mutect2, varscan2
- HUNK | c.1891C>T p.P631S | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0); catalogued as COSV99528876; called by muse, mutect2, varscan2
- HYAL4 | c.217C>T p.P73S | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV56138678; called by muse, mutect2, varscan2
- HYDIN | c.14570C>T p.P4857L | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101125200; called by muse, mutect2, varscan2
- HYDIN | c.13900-2A>G p.X4634_splice | Splice Site (SNP) | VAF 14/46 reads (30%) | catalogued as COSV101125164; called by muse, mutect2, varscan2
- HYDIN | c.5582C>T p.S1861F | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1406654893, COSV99993234; called by muse, varscan2
- IBTK | c.365C>T p.A122V | Missense Mutation (SNP) | VAF 35/110 reads (32%) | SIFT tolerated (0.88); PolyPhen benign (0.003); catalogued as COSV100091368; called by muse, mutect2, varscan2
- IDE | c.3017C>T p.P1006L | Missense Mutation (SNP) | VAF 25/121 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99794352; called by muse, mutect2, varscan2
- IFNA13 | c.182G>A p.G61E | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT tolerated (0.27); PolyPhen benign (0.02); catalogued as COSV101489513; called by muse, mutect2, varscan2
- IFNE | c.319G>A p.E107K | Missense Mutation (SNP) | VAF 26/98 reads (27%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.936); catalogued as COSV58643038; called by muse, mutect2, varscan2
- IFNG | c.73G>A p.D25N | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.29); PolyPhen benign (0.085); catalogued as COSV99971265; called by muse, mutect2, varscan2
- IFT140 | c.1406T>A p.L469H | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.711); catalogued as rs924912054, COSV101276601; called by muse, mutect2, varscan2
- IGFBP4 | c.439C>T p.R147* | Nonsense Mutation (SNP) | VAF 9/42 reads (21%) | catalogued as rs942618272, COSV54096838; called by muse, mutect2, varscan2
- IGHV3-23 | c.269C>T p.S90F | Missense Mutation (SNP) | VAF 67/388 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.842); catalogued as rs1555466937; called by muse, mutect2, varscan2
- IGSF1 | c.1454G>A p.S485N | Missense Mutation (SNP) | VAF 33/56 reads (59%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.977); catalogued as COSV100812284; called by muse, mutect2, varscan2
- IGSF10 | c.2257C>T p.P753S | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.634); catalogued as COSV99193076; called by muse, mutect2, varscan2
- IHH | c.991C>T p.P331S | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99838781; called by muse, mutect2, varscan2
- IL12B | c.128G>A p.G43E | Missense Mutation (SNP) | VAF 30/43 reads (70%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.886); catalogued as COSV51455271, COSV99180371; called by muse, mutect2, varscan2
- IL18R1 | c.1591G>A p.E531K | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.012); catalogued as rs766842885, COSV52123793; called by muse, mutect2, varscan2
- IL18RAP | c.1330A>T p.N444Y | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV99962359; called by muse, mutect2, varscan2
- IL1RL2 | c.938C>T p.P313L | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.285); catalogued as rs267598805, COSV99960105, COSV99961030; called by muse, mutect2, varscan2
- IL20RA | c.950C>T p.S317L | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100360193; called by muse, mutect2, varscan2
- IL36A | c.58C>T p.H20Y | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.497); catalogued as rs749638456, COSV52083307, COSV52083708; called by muse, mutect2, varscan2
- IL7R | c.425G>A p.G142E | Missense Mutation (SNP) | VAF 32/103 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV57412036; called by muse, mutect2, varscan2
- INCENP | c.928C>T p.P310S | Missense Mutation (SNP) | VAF 27/81 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs1565091987, COSV99611418; called by muse, mutect2, varscan2
- INPP4B | c.106C>T p.P36S | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0.022); catalogued as COSV99526376; called by muse, mutect2, varscan2
- INSL6 | c.415G>C p.V139L | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV101068521; called by muse, mutect2, varscan2
- IQCF2 | c.75G>A p.W25* | Nonsense Mutation (SNP) | VAF 9/35 reads (26%) | catalogued as COSV100291095; called by muse, mutect2, varscan2
- IRAK4 | c.304C>T p.P102S | Missense Mutation (SNP) | VAF 25/53 reads (47%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.625); catalogued as COSV71210527; called by muse, mutect2, varscan2
- IRF2 | c.856C>T p.P286S | Missense Mutation (SNP) | VAF 36/108 reads (33%) | SIFT tolerated (0.2); PolyPhen benign (0.056); catalogued as COSV101165886; called by muse, mutect2, varscan2
- ISX | c.256C>T p.R86C | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs372031013; called by muse, mutect2, varscan2
- ITFG2 | c.742C>T p.R248C | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as rs140247675; called by muse, varscan2
- ITIH2 | c.814G>A p.E272K | Missense Mutation (SNP) | VAF 34/116 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.08); catalogued as rs923997175, COSV64432565; called by muse, mutect2, varscan2
- ITIH5 | c.1465G>A p.D489N | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT tolerated (0.44); PolyPhen benign (0.043); catalogued as rs887329530, COSV53670082; called by muse, mutect2, varscan2
- ITLN2 | c.331C>T p.R111C | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.466); catalogued as rs200061193; called by muse, mutect2, varscan2
- ITPR2 | c.1235C>T p.P412L | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV101190131; called by muse, mutect2, varscan2
- ITSN1 | c.503C>T p.P168L | Missense Mutation (SNP) | VAF 25/65 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as COSV101180618; called by muse, mutect2, varscan2
- JADE1 | c.2228G>A p.S743N | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated (0.17); PolyPhen benign (0.431); catalogued as COSV99886192; called by muse, mutect2, varscan2
- JADE3 | c.134G>A p.R45Q | Missense Mutation (SNP) | VAF 23/46 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as rs1355562695, COSV99509937; called by muse, mutect2, varscan2
- JAK3 | c.2811G>A p.M937I | Missense Mutation (SNP) | VAF 27/98 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.763); catalogued as COSV101513007; called by muse, mutect2, varscan2
- JCAD | c.4054G>A p.D1352N | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100948535; called by muse, mutect2, varscan2
- JPT2 | c.515G>C p.R172P | Missense Mutation (SNP) | VAF 30/87 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99936238; called by muse, mutect2, varscan2
- KALRN | c.196C>T p.H66Y | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as COSV53752443, COSV99566920; called by muse, mutect2, varscan2
- KANK4 | c.40G>A p.D14N | Missense Mutation (SNP) | VAF 17/87 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as rs753716013, COSV62986172; called by muse, mutect2, varscan2
- KAT6B | c.5041G>A p.E1681K | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs1564632292, COSV54753335; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KCNB1 | c.490G>A p.D164N | Missense Mutation (SNP) | VAF 27/100 reads (27%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.767); catalogued as COSV100870403; called by muse, mutect2, varscan2
- KCNB2 | c.353C>T p.S118L | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.364); catalogued as COSV73049213; called by muse, mutect2, varscan2
- KCNH4 | c.464C>T p.S155F | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as COSV99236944, COSV99237799; called by muse, mutect2, varscan2
- KCNH5 | c.2185C>T p.P729S | Missense Mutation (SNP) | VAF 22/86 reads (26%) | SIFT tolerated (0.98); PolyPhen benign (0); catalogued as COSV100527851; called by muse, mutect2, varscan2
- KCNH7 | c.2896G>A p.D966N | Missense Mutation (SNP) | VAF 25/140 reads (18%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs370772173, COSV100147559; called by muse, mutect2, varscan2
- KCNH7 | c.793G>A p.E265K | Missense Mutation (SNP) | VAF 28/108 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.211); catalogued as rs1428198012, COSV59809707; called by muse, mutect2, varscan2
- KCNH7 | c.680C>T p.P227L | Missense Mutation (SNP) | VAF 26/98 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.011); catalogued as COSV100037642, COSV59816324; called by muse, mutect2, varscan2
- KCNJ10 | c.400C>T p.R134C | Missense Mutation (SNP) | VAF 42/108 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100927949; called by muse, mutect2, varscan2
- KCNJ15 | c.949C>T p.L317F | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.971); catalogued as COSV100154367; called by muse, mutect2, varscan2
- KCNK18 | c.741G>A p.M247I | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT tolerated (0.68); PolyPhen benign (0.001); catalogued as COSV57972283; called by muse, mutect2, varscan2
- KCNK5 | c.757C>T p.H253Y | Missense Mutation (SNP) | VAF 17/84 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.397); catalogued as COSV100851919; called by muse, mutect2, varscan2
- KCNQ5 | c.271G>A p.G91R | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.288); catalogued as COSV100572911; called by muse, mutect2, varscan2
- KCNQ5 | c.862G>A p.E288K | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV59651143; called by muse, mutect2, varscan2
- KCNT2 | c.324G>A p.Q108= | Splice Region (SNP) | VAF 9/46 reads (20%) | catalogued as COSV99656284; called by muse, mutect2, varscan2
- KDM2B | c.1348C>T p.P450S | Missense Mutation (SNP) | VAF 41/67 reads (61%) | SIFT tolerated (0.72); PolyPhen benign (0.007); catalogued as COSV65646162; called by muse, mutect2, varscan2
- KIAA0100 | c.1135C>T p.H379Y | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs769001605, COSV101197394; called by muse, mutect2, varscan2
- KIAA1109 | c.14236G>A p.E4746K | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.995); catalogued as COSV99165477; called by muse, mutect2, varscan2
- KIAA1549L | c.873G>T p.E291D (on ENST00000321505; = p.E588D on NM_012194.3) | Missense Mutation (SNP) | VAF 22/118 reads (19%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.967); catalogued as COSV99684296; called by muse, mutect2, varscan2
- KIF11 | c.3034T>A p.F1012I | Missense Mutation (SNP) | VAF 24/96 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99586123; called by muse, mutect2, varscan2
- KIF13A | c.3710C>T p.S1237F | Missense Mutation (SNP) | VAF 15/87 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV99437817; called by muse, mutect2, varscan2
- KIF16B | c.1423G>A p.E475K | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100734826; called by muse, mutect2, varscan2
- KIF1A | c.3165C>A p.I1055= | Splice Region (SNP) | VAF 29/114 reads (25%) | catalogued as COSV100242150; called by muse, mutect2, varscan2
- KIF2B | c.512G>A p.R171Q | Missense Mutation (SNP) | VAF 18/87 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.086); catalogued as rs746185699, COSV52129583; called by muse, mutect2, varscan2
- KIR2DL1 | c.869A>T p.E290V | Missense Mutation (SNP) | VAF 42/131 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.653); catalogued as COSV99383555; called by muse, mutect2, varscan2
- KIR3DL1 | c.214C>T p.H72Y | Missense Mutation (SNP) | VAF 26/108 reads (24%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as COSV58493109; called by muse, mutect2, varscan2
- KLHL1 | c.1589C>T p.T530I | Missense Mutation (SNP) | VAF 26/81 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); catalogued as rs1220393563, COSV100918010; called by muse, mutect2, varscan2
- KMT2B | c.755C>T p.P252L | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as COSV99386233; called by muse, mutect2
- KRT35 | c.265G>A p.G89R | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated (0.26); PolyPhen benign (0.006); catalogued as COSV99877895; called by muse, mutect2, varscan2
- KRT82 | c.625G>A p.E209K | Missense Mutation (SNP) | VAF 42/65 reads (65%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); catalogued as rs1180137073, COSV99233426, COSV99233835; called by muse, mutect2, varscan2
- KRT9 | c.808G>A p.E270K | Missense Mutation (SNP) | VAF 31/117 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.089); catalogued as COSV99879022; called by muse, mutect2, varscan2
- KRTAP12-4 | c.158C>T p.S53F | Missense Mutation (SNP) | VAF 21/35 reads (60%) | SIFT deleterious (0); PolyPhen benign (0.192); catalogued as COSV59979782; called by muse, mutect2, varscan2
- KRTAP3-2 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 16/55 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.878); catalogued as COSV101196043; called by muse, mutect2, varscan2
- LAMA1 | c.313C>T p.H105Y | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101057279; called by muse, mutect2, varscan2
- LAMA5 | c.3176C>T p.A1059V | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.41); PolyPhen benign (0.122); catalogued as COSV99441892; called by muse, mutect2, varscan2
- LAMC2 | c.382T>G p.C128G | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as COSV99917854; called by muse, varscan2
- LAMP5 | c.691G>A p.E231K | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.323); catalogued as COSV55714950, COSV99855678; called by muse, mutect2, varscan2
- LCK | c.1195+1G>A p.X399_splice | Splice Site (SNP) | VAF 30/67 reads (45%) | catalogued as COSV100288056; called by muse, mutect2, varscan2
- LCOR | c.3727C>T p.P1243S | Missense Mutation (SNP) | VAF 28/101 reads (28%) | SIFT tolerated (0.09); PolyPhen probably damaging (1); catalogued as COSV53715139, COSV53718587; called by muse, mutect2, varscan2
- LDB2 | c.788C>T p.S263F | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58767584; called by muse, mutect2, varscan2
- LEMD3 | c.1231C>T p.P411S | Missense Mutation (SNP) | VAF 28/61 reads (46%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs766191006, COSV100384562; called by muse, mutect2, varscan2
- LEPR | c.1243G>A p.E415K | Missense Mutation (SNP) | VAF 25/55 reads (45%) | SIFT tolerated (0.12); PolyPhen benign (0.345); catalogued as COSV100756730; called by muse, mutect2, varscan2
- LGSN | c.649G>A p.E217K | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.879); catalogued as rs369924426, COSV101040536; called by muse, mutect2, varscan2
- LHX6 | c.529G>A p.E177K (on ENST00000373755 / NM_001242334.2; = p.E206K on NM_014368.5) | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.752); catalogued as COSV100493475, COSV100493576; called by muse, mutect2, varscan2
- LILRA4 | c.1009G>A p.G337R | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99393338; called by muse, mutect2, varscan2
- LILRA4 | c.166C>T p.Q56* | Nonsense Mutation (SNP) | VAF 29/104 reads (28%) | catalogued as COSV99393339; called by muse, mutect2, varscan2
- LILRA5 | c.835C>T p.L279F | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.921); catalogued as COSV100007061; called by muse, mutect2, varscan2
- LILRB2 | c.395C>T p.P132L | Missense Mutation (SNP) | VAF 30/99 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.596); catalogued as COSV100079595, COSV58749456; called by muse, mutect2, varscan2
- LIMCH1 | c.2770G>A p.E924K | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT tolerated (0.69); PolyPhen probably damaging (0.979); catalogued as rs775542476, COSV100574305; called by muse, mutect2, varscan2
- LMAN1 | c.1121G>A p.G374E | Missense Mutation (SNP) | VAF 52/193 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.101); catalogued as COSV99195364; called by muse, mutect2, varscan2
- LONRF2 | c.1020G>A p.M340I | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV101111041; called by muse, mutect2, varscan2
- LPAR1 | c.1039T>C p.S347P | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT tolerated (0.21); PolyPhen benign (0.045); catalogued as COSV100730999; called by muse, varscan2
- LPIN2 | c.2113C>T p.P705S | Missense Mutation (SNP) | VAF 28/81 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99858886; called by muse, mutect2, varscan2
- LRCH1 | c.697C>T p.L233F | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.201); catalogued as rs1323566040, COSV100244015; called by muse, mutect2
- LRP1B | c.11620C>T p.Q3874* | Nonsense Mutation (SNP) | VAF 14/70 reads (20%) | catalogued as COSV67213919; called by muse, mutect2, varscan2
- LRP1B | c.10060G>A p.E3354K | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.836); catalogued as COSV101251928; called by muse, mutect2, varscan2
- LRP1B | c.4840G>A p.D1614N | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.883); catalogued as rs762458785, COSV67183175, COSV67187424; called by muse, mutect2, varscan2
- LRP1B | c.3928G>A p.D1310N | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1447035945, COSV101260002; called by muse, varscan2
- LRP2 | c.12076G>A p.G4026R | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99789967; called by muse, mutect2, varscan2
- LRP4 | c.2278G>A p.E760K | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT tolerated (0.63); PolyPhen benign (0.003); catalogued as COSV101066832; called by muse, mutect2, varscan2
- LRP6 | c.1156C>T p.R386C | Missense Mutation (SNP) | VAF 31/75 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs148238873; called by muse, mutect2, varscan2
- LRRC27 | c.1400C>T p.A467V | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as COSV100889911; called by muse, mutect2, varscan2
- LRRC37A2 | c.3737C>T p.S1246F | Missense Mutation (SNP) | VAF 24/117 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV100238829, COSV61002711; called by muse, mutect2, varscan2
- LRRC41 | c.286G>A p.G96S | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100586539; called by muse, mutect2, varscan2
- LRRC43 | c.304A>T p.N102Y | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.321); catalogued as COSV100336916; called by muse, mutect2, varscan2
- LRRIQ3 | c.1212G>A p.M404I | Missense Mutation (SNP) | VAF 50/113 reads (44%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV100598647, COSV63048063; called by muse, mutect2, varscan2
- LRRTM1 | c.1265C>T p.A422V | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated (0.51); PolyPhen benign (0.185); catalogued as COSV99703023; called by muse, mutect2, varscan2
- LRRTM4 | c.559G>A p.D187N | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV101297710; called by muse, mutect2, varscan2
- LTBP1 | c.1827G>A p.M609I (on ENST00000404816 / NM_206943.4; = p.M283I on NM_000627.4) | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as COSV100617869; called by muse, mutect2, varscan2
- LTBP1 | c.4153G>A p.E1385K (on ENST00000404816 / NM_206943.4; = p.E1059K on NM_000627.4) | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs774714743, COSV55379298, COSV99697579; called by muse, mutect2, varscan2
- LTBP3 | c.1366C>T p.P456S | Missense Mutation (SNP) | VAF 26/98 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100100240; called by muse, mutect2, varscan2
- MAB21L1 | c.271G>A p.D91N | Missense Mutation (SNP) | VAF 24/98 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1428309411, COSV100083467; called by muse, mutect2, varscan2
- MAGEB18 | c.646G>A p.E216K | Missense Mutation (SNP) | VAF 9/14 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100305603, COSV57463656; called by muse, mutect2, varscan2
- MAGEC1 | c.106C>T p.Q36* | Nonsense Mutation (SNP) | VAF 60/96 reads (63%) | catalogued as COSV53579687, COSV99596385; called by muse, mutect2, varscan2
- MAGEC3 | c.1693G>A p.E565K | Missense Mutation (SNP) | VAF 36/61 reads (59%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.705); catalogued as rs772070241, COSV100025227, COSV68924260; called by muse, mutect2, varscan2
- MAGI1 | c.901C>T p.P301S | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV58346924; called by muse, mutect2, varscan2
- MAN1A2 | c.1868C>T p.P623L | Missense Mutation (SNP) | VAF 33/132 reads (25%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.87); catalogued as COSV100741036; called by muse, mutect2, varscan2
- MAOA | c.684A>T p.E228D | Missense Mutation (SNP) | VAF 21/33 reads (64%) | SIFT deleterious (0.04); PolyPhen benign (0.011); catalogued as COSV100108973; called by muse, mutect2, varscan2
- MAP3K13 | c.2005A>C p.N669H | Missense Mutation (SNP) | VAF 42/133 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV99407806; called by muse, mutect2, varscan2
- MAP3K21 | c.1553-1G>A p.X518_splice | Splice Site (SNP) | VAF 29/77 reads (38%) | catalogued as COSV100786151; called by muse, mutect2, varscan2
- MAP3K21 | c.2329C>T p.P777S | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV100786154; called by muse, mutect2, varscan2
- MAP3K21 | c.2506C>T p.P836S | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.026); catalogued as COSV100786155; called by muse, mutect2, varscan2
- MAP3K3 | c.157G>A p.G53R | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.597); catalogued as rs149314666; called by muse, mutect2, varscan2
- MAP3K9 | c.2972T>G p.F991C (on ENST00000554752 / NM_001284230.1; = p.F1005C on NM_033141.4) | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.785); catalogued as COSV101173744; called by muse, mutect2, varscan2
- MAP4K2 | c.199G>A p.E67K | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.796); catalogued as COSV99581577; called by muse, mutect2, varscan2
- MAPK10 | c.676C>T p.P226S (on ENST00000359221 / NM_001351625.2; = p.P264S on NM_002753.5) | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.477); catalogued as COSV60385282; called by muse, mutect2, varscan2
- MAPK4 | c.916G>A p.G306R | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); catalogued as COSV68543358; called by muse, mutect2, varscan2
- MARCHF11 | c.805C>T p.P269S | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs1560971787, COSV100198218, COSV60133271; called by muse, mutect2, varscan2
- MAS1 | c.662C>T p.S221F | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT tolerated (0.75); PolyPhen benign (0.012); catalogued as COSV99396984; called by muse, mutect2, varscan2
- MCF2 | c.1660G>A p.E554K | Missense Mutation (SNP) | VAF 30/51 reads (59%) | SIFT tolerated (0.08); PolyPhen benign (0.221); catalogued as COSV100645056; called by muse, mutect2, varscan2
- MCM4 | c.1835C>T p.S612F | Missense Mutation (SNP) | VAF 31/67 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100031813; called by muse, mutect2, varscan2
- MCTP2 | c.1462G>A p.E488K | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs755280601, COSV100537685; called by muse, mutect2, varscan2
- MDN1 | c.7120G>A p.V2374I | Missense Mutation (SNP) | VAF 15/101 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.152); catalogued as COSV101021756; called by muse, mutect2, varscan2
- MDN1 | c.3589C>T p.P1197S | Missense Mutation (SNP) | VAF 30/124 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101021758; called by muse, mutect2, varscan2
- MECOM | c.776G>A p.G259E (on ENST00000468789 / NM_001105078.4; = p.G447E on NM_004991.4) | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.999); catalogued as COSV52963956, COSV99245238; called by muse, mutect2, varscan2
- MED12L | c.5917C>T p.P1973S | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT tolerated, low confidence (0.87); PolyPhen benign (0.005); catalogued as COSV56393261, COSV99854407; called by muse, mutect2, varscan2
- MEF2C | c.287G>T p.C96F | Missense Mutation (SNP) | VAF 41/114 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.438); catalogued as COSV100424707; called by muse, mutect2, varscan2
- MEIS3 | c.710G>A p.G237E | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.932); catalogued as COSV100520540; called by muse, mutect2
- MEP1B | c.1973C>T p.S658L | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV52496930; called by muse, mutect2, varscan2
- MFSD6 | c.1207G>A p.G403R | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV99855365; called by muse, mutect2, varscan2
- MGAM | c.4610C>T p.S1537F | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101527718, COSV72076134; called by muse, mutect2, varscan2
- MGAM | c.4724G>A p.G1575E | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs756724019, COSV101527719; called by muse, mutect2, varscan2
- MGAT4B | c.266C>T p.T89I | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.505); catalogued as COSV99482373; called by muse, mutect2
- MIA2 | c.548C>T p.A183V | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV99696903; called by muse, mutect2, varscan2
- MIIP | c.856C>T p.P286S | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99337744; called by muse, mutect2, varscan2
- MLIP | c.503C>T p.S168F | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.834); catalogued as COSV51438111; called by muse, mutect2, varscan2
- MLLT3 | c.1052C>G p.T351R | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT tolerated (0.32); PolyPhen benign (0.092); catalogued as COSV100581529; called by muse, mutect2, varscan2
- MMD2 | c.664G>A p.G222S (on ENST00000404774 / NM_001100600.2; = p.G198S on NM_198403.4) | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101287112, COSV68661556; called by muse, mutect2, varscan2
- MME | c.244G>A p.D82N | Missense Mutation (SNP) | VAF 27/92 reads (29%) | SIFT tolerated (0.66); PolyPhen benign (0.04); catalogued as COSV100852510; called by muse, mutect2, varscan2
- MME | c.878G>A p.R293Q | Missense Mutation (SNP) | VAF 24/51 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs1157455203, COSV64707508; called by muse, mutect2, varscan2
- MME | c.1131G>A p.M377I | Missense Mutation (SNP) | VAF 22/83 reads (27%) | SIFT tolerated (0.17); PolyPhen benign (0.087); catalogued as COSV100852511, COSV64710834; called by muse, mutect2, varscan2
- MMP9 | c.2119G>A p.D707N | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0.003); catalogued as COSV100812450; called by muse, mutect2, varscan2
- MOCOS | c.1403C>T p.S468L | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs754636835, COSV99733827; called by muse, mutect2, varscan2
- MOGAT3 | c.982G>A p.E328K | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated (0.27); PolyPhen benign (0.018); catalogued as COSV56174561; called by muse, mutect2, varscan2
- MOV10 | c.1432C>T p.P478S | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1557766727, COSV100659752; called by muse, mutect2, varscan2
- MPDZ | c.4972G>A p.E1658K | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.779); catalogued as COSV100057382, COSV59927578; called by muse, mutect2, varscan2
- MRC2 | c.4376C>T p.P1459L | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT tolerated (0.21); PolyPhen benign (0.053); catalogued as COSV100316686; called by muse, mutect2, varscan2
- MROH2B | c.2495A>T p.N832I | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.424); catalogued as COSV101270888; called by muse, mutect2
- MROH2B | c.921C>T p.A307= | Splice Region (SNP) | VAF 21/60 reads (35%) | catalogued as COSV101270889; called by muse, mutect2, varscan2
- MROH7 | c.1370C>T p.T457I | Missense Mutation (SNP) | VAF 18/105 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as COSV100273948; called by muse, mutect2, varscan2
- MRPS2 | c.668T>C p.V223A | Missense Mutation (SNP) | VAF 19/77 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99613647; called by muse, mutect2, varscan2
- MSR1 | c.274G>A p.D92N | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT tolerated (0.31); PolyPhen benign (0.006); catalogued as rs1337591212, COSV100027929, COSV50529421; called by muse, mutect2, varscan2
- MUC16 | c.39614C>T p.P13205L | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.967); catalogued as rs1258132777, COSV101110059; called by muse, mutect2, varscan2
- MUC16 | c.39613C>T p.P13205S | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT tolerated, low confidence (0.14); PolyPhen probably damaging (0.954); catalogued as rs1395559619, COSV101110060, COSV66692081; called by muse, mutect2, varscan2
- MUC16 | c.36463C>T p.L12155F | Missense Mutation (SNP) | VAF 42/155 reads (27%) | SIFT tolerated, low confidence (0.86); PolyPhen benign (0.019); catalogued as COSV101201225; called by muse, mutect2, varscan2
- MUC16 | c.30467G>A p.G10156E | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT tolerated, low confidence (0.87); PolyPhen benign (0.017); catalogued as COSV101201227; called by muse, mutect2, varscan2
- MUC16 | c.12928C>T p.Q4310* | Nonsense Mutation (SNP) | VAF 12/44 reads (27%) | catalogued as COSV101201245; called by muse, mutect2, varscan2
- MUC16 | c.11905C>T p.P3969S | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.031); catalogued as COSV101201247; called by muse, mutect2
- MUC16 | c.11413C>T p.P3805S | Missense Mutation (SNP) | VAF 34/167 reads (20%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.02); catalogued as rs755804965, COSV67457852; called by muse, mutect2, varscan2
- MUC16 | c.8756A>C p.D2919A | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.017); catalogued as COSV101201250; called by muse, mutect2, varscan2
- MUC16 | c.3136T>A p.Y1046N | Missense Mutation (SNP) | VAF 32/94 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.006); catalogued as COSV101201253; called by muse, mutect2, varscan2
- MUC17 | c.3188C>T p.S1063L | Missense Mutation (SNP) | VAF 109/292 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as rs1202766556, COSV100074816; called by muse, mutect2, varscan2
- MUC2 | c.1561G>A p.D521N | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.11); catalogued as rs772822306; called by muse, mutect2, varscan2
- MUC5B | c.7873G>A p.G2625R | Missense Mutation (SNP) | VAF 42/135 reads (31%) | SIFT tolerated (0.15); PolyPhen benign (0.096); catalogued as COSV101500079, COSV71590705; called by muse, mutect2, varscan2
- MXRA5 | c.6016G>A p.E2006K | Missense Mutation (SNP) | VAF 18/25 reads (72%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.488); catalogued as COSV54230410; called by muse, mutect2, varscan2
- MXRA5 | c.4627C>T p.P1543S | Missense Mutation (SNP) | VAF 45/73 reads (62%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as COSV99478887, COSV99479966; called by muse, mutect2, varscan2
- MYADM | c.65C>T p.S22F | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.598); catalogued as COSV100425179; called by muse, mutect2, varscan2
- MYCBP2 | c.6231T>G p.N2077K (on ENST00000357337; = p.N2115K on NM_015057.5) | Missense Mutation (SNP) | VAF 20/95 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV100631567; called by muse, mutect2, varscan2
- MYH2 | c.3437C>T p.S1146F | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as rs1208708711, COSV99820804; called by muse, mutect2, varscan2
- MYH2 | c.776G>A p.G259E | Missense Mutation (SNP) | VAF 34/96 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99820806; called by muse, mutect2, varscan2
- MYH8 | c.2934G>A p.V978= | Splice Region (SNP) | VAF 40/94 reads (43%) | catalogued as COSV67963103; called by muse, mutect2, varscan2
- MYO18B | c.680G>A p.G227E | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated, low confidence (0.26); PolyPhen possibly damaging (0.563); catalogued as COSV59140619; called by muse, mutect2, varscan2
- MYO1D | c.2590C>T p.R864C | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.94); catalogued as rs756724289, COSV100554289, COSV59024523; called by muse, mutect2, varscan2
- MYO1F | c.1918G>A p.E640K | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT tolerated (0.54); PolyPhen benign (0.18); catalogued as rs1175655074, COSV100597014; called by muse, mutect2, varscan2
- MYO1F | c.1789G>A p.E597K | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.833); catalogued as COSV100597015; called by mutect2, varscan2
- MYO6 | c.3168-1G>A p.X1056_splice (on ENST00000369981; = p.X1046_splice on NM_004999.4) | Splice Site (SNP) | VAF 8/47 reads (17%) | catalogued as COSV100889410; called by muse, mutect2, varscan2
- MYO7B | c.140G>A p.W47* | Nonsense Mutation (SNP) | VAF 16/31 reads (52%) | catalogued as rs1223447245, COSV101268363; called by muse, mutect2, varscan2
- MYO9B | c.3424C>T p.P1142S | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT tolerated (0.4); PolyPhen benign (0.031); catalogued as COSV68283118; called by muse, mutect2, varscan2
- MYOCD | c.328G>A p.E110K | Missense Mutation (SNP) | VAF 32/85 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.278); catalogued as COSV58500125; called by muse, mutect2, varscan2
- MYPN | c.1789C>T p.R597C | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as rs367570424; called by muse, mutect2, varscan2
- N4BP2 | c.3065T>C p.F1022S | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV99789174; called by muse, mutect2, varscan2
- NADSYN1 | c.640G>T p.D214Y | Missense Mutation (SNP) | VAF 19/90 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV100034998; called by muse, mutect2, varscan2
- NAGLU | c.638C>T p.P213L | Missense Mutation (SNP) | VAF 30/97 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV99864335; called by muse, mutect2, varscan2
- NALCN | c.3255G>A p.W1085* | Nonsense Mutation (SNP) | VAF 18/59 reads (31%) | catalogued as rs765672913, COSV99217245; called by muse, mutect2, varscan2
- NASP | c.2167G>A p.E723K | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.937); catalogued as COSV100601974; called by muse, mutect2, varscan2
- NAV2 | c.7086G>C p.W2362C (on ENST00000396087 / NM_001244963.2; = p.W2303C on NM_145117.5) | Missense Mutation (SNP) | VAF 54/188 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100217568; called by muse, mutect2, varscan2
- NCF2 | c.589G>A p.D197N | Missense Mutation (SNP) | VAF 40/177 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.096); catalogued as COSV100838939; called by muse, mutect2, varscan2
- NCMAP | c.202G>A p.G68S | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs764863649, COSV65557646; called by muse, mutect2, varscan2
- NDN | c.167C>T p.P56L | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs1197227096, COSV100086684; called by muse, mutect2, varscan2
- NDRG4 | c.791G>A p.G264E (on ENST00000570248 / NM_001378344.1; = p.G296E on NM_020465.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 27/94 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV99262506; called by muse, mutect2, varscan2
- NEBL | c.1043G>A p.G348E | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV101009326; called by muse, mutect2, varscan2
- NELFA | c.668-7C>T | Splice Region (SNP) | VAF 4/12 reads (33%) | catalogued as rs1025161769, COSV100373800; called by muse, mutect2, varscan2
- NEXMIF | c.3647C>T p.S1216F | Missense Mutation (SNP) | VAF 29/42 reads (69%) | SIFT deleterious (0.02); PolyPhen benign (0.091); catalogued as COSV99281638; called by muse, mutect2, varscan2
- NFKB2 | c.833C>T p.P278L | Missense Mutation (SNP) | VAF 29/100 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99193759; called by muse, mutect2, varscan2
- NHSL2 | c.1268C>T p.S423F (on ENST00000510661; = p.S789F on NM_001013627.2) | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT deleterious (0); PolyPhen benign (0.259); catalogued as COSV101030296, COSV65454256; called by muse, varscan2
- NIPBL | c.4391C>T p.P1464L | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99242300; called by muse, mutect2, varscan2
- NIPSNAP3A | c.649C>T p.P217S | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (0.22); PolyPhen benign (0.062); catalogued as COSV101046473; called by muse, mutect2
- NLRP10 | c.1942G>A p.E648K | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (0.23); PolyPhen benign (0.005); catalogued as rs1380941090, COSV60780668; called by muse, mutect2, varscan2
- NLRP13 | c.487C>T p.P163S | Missense Mutation (SNP) | VAF 21/91 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.01); catalogued as COSV100738461; called by muse, mutect2, varscan2
- NLRP3 | c.1333C>T p.L445F | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.659); catalogued as rs202121800, COSV100275451, COSV100276545; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NLRP4 | c.238G>A p.D80N | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV100016320; called by muse, mutect2, varscan2
- NOS1 | c.2804G>A p.W935* | Nonsense Mutation (SNP) | VAF 31/62 reads (50%) | catalogued as COSV100501285; called by muse, mutect2, varscan2
- NPEPPS | c.1111C>T p.L371F | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100443931; called by muse, mutect2, varscan2
- NPHS1 | c.3553C>T p.P1185S | Missense Mutation (SNP) | VAF 31/88 reads (35%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.738); catalogued as rs867310471, COSV62289531; called by muse, mutect2, varscan2
- NPNT | c.440G>A p.G147E | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.573); catalogued as COSV59755944; called by muse, mutect2, varscan2
- NPY5R | c.544G>A p.E182K | Missense Mutation (SNP) | VAF 46/166 reads (28%) | SIFT tolerated (0.31); PolyPhen benign (0.062); catalogued as COSV58454508; called by muse, mutect2, varscan2
- NR1H4 | c.215C>T p.S72F (on ENST00000551379 / NM_001206993.2; = p.S62F on NM_005123.4) | Missense Mutation (SNP) | VAF 32/56 reads (57%) | SIFT deleterious (0); PolyPhen benign (0.072); catalogued as rs868079755, COSV51849579; called by muse, mutect2, varscan2
- NRXN3 | c.1159C>T p.P387S (on ENST00000335750 / NM_001330195.2; = p.P14S on NM_004796.6) | Missense Mutation (SNP) | VAF 33/108 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as COSV100207106, COSV100208109; called by muse, mutect2, varscan2
- NUGGC | c.1869G>A p.W623* | Nonsense Mutation (SNP) | VAF 29/76 reads (38%) | catalogued as COSV100429712, COSV58435615; called by muse, mutect2, varscan2
- NUP214 | c.1498C>T p.P500S | Missense Mutation (SNP) | VAF 33/120 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.028); catalogued as COSV100845381; called by muse, mutect2, varscan2
- NUP58 | c.855A>T p.E285D | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT tolerated (0.39); PolyPhen benign (0.026); catalogued as COSV101098881; called by muse, mutect2, varscan2
- NUP98 | c.3262C>T p.P1088S (on ENST00000359171 / NM_001365126.1; = p.P1071S on NM_016320.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT tolerated (0.55); PolyPhen benign (0.001); catalogued as COSV100263312; called by muse, mutect2, varscan2
- NUP98 | c.610C>T p.R204C | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs868315533, COSV61435326; called by muse, mutect2
- NXPH1 | c.217G>A p.D73N | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV101339578; called by muse, mutect2, varscan2
- OAS1 | c.1130C>T p.S377F | Missense Mutation (SNP) | VAF 39/57 reads (68%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.094); catalogued as COSV99177259; called by muse, mutect2, varscan2
- OCA2 | c.341C>T p.P114L | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.169); catalogued as COSV100668545; called by muse, mutect2, varscan2
- OLFM3 | c.181C>T p.P61S (on ENST00000338858 / NM_001288821.1; = p.P41S on NM_058170.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 36/74 reads (49%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs778515368, COSV100129976; called by muse, mutect2, varscan2
- OLFM4 | c.1334C>T p.T445I | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.316); catalogued as COSV99524535; called by muse, mutect2, varscan2
- OPLAH | c.694G>A p.G232R | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101470892; called by muse, mutect2, varscan2
- OR10AG1 | c.671G>A p.G224E | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV56631994; called by muse, mutect2, varscan2
- OR10G3 | c.619G>A p.V207M | Missense Mutation (SNP) | VAF 32/113 reads (28%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.993); catalogued as COSV100336137; called by muse, mutect2, varscan2
- OR10H2 | c.354G>A p.M118I | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.643); catalogued as rs1234135845, COSV100008866; called by muse, mutect2, varscan2
- OR10H5 | c.61C>T p.P21S | Missense Mutation (SNP) | VAF 30/108 reads (28%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.45); catalogued as COSV100454786; called by muse, mutect2, varscan2
- OR10T2 | c.151C>T p.R51C | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as rs371572112; called by muse, mutect2, varscan2
- OR11G2 | c.1031G>A p.G344E | Missense Mutation (SNP) | VAF 22/94 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.162); catalogued as COSV100640041; called by muse, mutect2
- OR11L1 | c.805G>A p.E269K | Missense Mutation (SNP) | VAF 30/67 reads (45%) | SIFT tolerated (0.37); PolyPhen benign (0.196); catalogued as rs866164111, COSV63313503; called by muse, mutect2, varscan2
- OR12D2 | c.272C>T p.S91F | Missense Mutation (SNP) | VAF 45/80 reads (56%) | SIFT deleterious (0); PolyPhen benign (0.32); catalogued as COSV65827087, COSV65828278; called by muse, mutect2, varscan2
- OR1L4 | c.419G>A p.W140* | Nonsense Mutation (SNP) | VAF 47/159 reads (30%) | catalogued as rs781502694, COSV99413940; called by muse, mutect2, varscan2
- OR1L8 | c.91C>T p.L31F | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.009); catalogued as rs147109810, COSV100508665; called by muse, mutect2
- OR2A2 | c.694G>A p.G232S | Missense Mutation (SNP) | VAF 25/110 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV101286668; called by muse, mutect2, varscan2
- OR2A25 | c.619G>T p.V207L | Missense Mutation (SNP) | VAF 25/94 reads (27%) | SIFT tolerated (0.25); PolyPhen benign (0.026); catalogued as rs763465311, COSV101376413; called by muse, mutect2, varscan2
- OR2A25 | c.706G>T p.A236S | Missense Mutation (SNP) | VAF 29/100 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV101376414; called by muse, mutect2, varscan2
- OR2B2 | c.829T>A p.F277I | Missense Mutation (SNP) | VAF 19/101 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.761); catalogued as COSV100308215; called by muse, mutect2, varscan2
- OR2F2 | c.860C>T p.P287L | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101283846; called by muse, mutect2, varscan2
- OR2L13 | c.197C>T p.S66F | Missense Mutation (SNP) | VAF 46/157 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100813875, COSV99050220; called by muse, mutect2, varscan2
- OR3A3 | c.953G>A p.R318Q | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT tolerated (0.32); PolyPhen benign (0.01); catalogued as rs375267018; called by muse, mutect2, varscan2
- OR4E2 | c.278C>T p.S93F | Missense Mutation (SNP) | VAF 57/190 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.238); catalogued as rs866396121, COSV57731749; called by muse, mutect2, varscan2
- OR4P4 | c.274T>C p.Y92H | Missense Mutation (SNP) | VAF 30/104 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV100111833; called by muse, mutect2, varscan2
- OR4S1 | c.541C>T p.P181S | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as rs866149383, COSV60679676, COSV60679764; called by muse, mutect2, varscan2
- OR51B5 | c.422A>C p.K141T | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.168); catalogued as COSV100332657; called by muse, mutect2, varscan2
- OR51E1 | c.10G>A p.D4N | Missense Mutation (SNP) | VAF 25/70 reads (36%) | SIFT tolerated (0.51); PolyPhen benign (0.046); catalogued as rs867900802, COSV101211541; called by muse, mutect2, varscan2
- OR51E1 | c.184A>G p.M62V | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV101211542; called by muse, mutect2, varscan2
- OR51F1 | c.24G>A p.M8I | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV100598890; called by muse, mutect2, varscan2
- OR52K1 | c.94C>T p.P32S | Missense Mutation (SNP) | VAF 27/103 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.043); catalogued as rs752131811, COSV100297734, COSV56903462; called by muse, mutect2, varscan2
- OR52K1 | c.95C>T p.P32L | Missense Mutation (SNP) | VAF 27/99 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.632); catalogued as rs1358029492, COSV100297735; called by muse, mutect2, varscan2
- OR5F1 | c.650C>A p.S217Y | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV99558467; called by muse, mutect2, varscan2
- OR5H14 | c.482G>A p.G161E | Missense Mutation (SNP) | VAF 45/194 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.493); catalogued as COSV101454343, COSV71193561; called by muse, mutect2, varscan2
- OR5H2 | c.514A>G p.T172A | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.803); catalogued as COSV100788812; called by muse, mutect2, varscan2
- OR6C4 | c.710C>T p.S237F | Missense Mutation (SNP) | VAF 53/83 reads (64%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.169); catalogued as COSV67792860; called by muse, mutect2, varscan2
- OR6S1 | c.64C>T p.L22F | Missense Mutation (SNP) | VAF 24/119 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.068); catalogued as COSV100289497; called by muse, mutect2, varscan2
- OR6V1 | c.311C>T p.S104F | Missense Mutation (SNP) | VAF 24/112 reads (21%) | SIFT tolerated (0.21); PolyPhen benign (0.031); catalogued as COSV69236971, COSV69237725; called by muse, mutect2, varscan2
- OR7G1 | c.29C>T p.S10L | Missense Mutation (SNP) | VAF 30/95 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.026); catalogued as COSV99528759; called by muse, mutect2, varscan2
- OR8B12 | c.665C>T p.S222F | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.25); catalogued as COSV100172921; called by muse, mutect2, varscan2
- OR8I2 | c.410C>T p.S137F | Missense Mutation (SNP) | VAF 24/96 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs1263273341, COSV100136244; called by muse, mutect2, varscan2
- OR8K3 | c.442C>T p.P148S | Missense Mutation (SNP) | VAF 28/81 reads (35%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.053); catalogued as rs1396981354, COSV57132100; called by muse, mutect2, varscan2
- OSMR | c.839C>T p.S280L | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.644); catalogued as rs769344392, COSV57085792; called by muse, mutect2, varscan2
- OTUD7A | c.1825G>A p.E609K (on ENST00000307050 / NM_001382637.1; = p.E602K on NM_130901.3) | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.033); catalogued as COSV100193129; called by muse, mutect2
- OVOL2 | c.326C>T p.T109I | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV99602583; called by muse, mutect2, varscan2
- P3H2 | c.1175C>T p.S392L | Missense Mutation (SNP) | VAF 31/141 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV100078349; called by muse, mutect2, varscan2
- PAH | c.1093C>T p.L365F | Missense Mutation (SNP) | VAF 28/73 reads (38%) | SIFT tolerated (0.18); PolyPhen benign (0.393); catalogued as rs951540129, COSV100188380; called by muse, mutect2, varscan2
- PAK4 | c.683C>G p.A228G | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.38); PolyPhen benign (0.202); catalogued as COSV100426594; called by muse, mutect2
- PALM2AKAP2 | c.840G>A p.M280I (on ENST00000374531 / NM_001037293.2; = p.M312I on NM_053016.6) | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); catalogued as rs1181980392, COSV57119104; called by muse, mutect2, varscan2
- PARM1 | c.265G>A p.E89K | Missense Mutation (SNP) | VAF 25/99 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0.018); catalogued as COSV100268489; called by muse, mutect2, varscan2
- PARP4 | c.3919C>T p.P1307S | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV101131990; called by muse, mutect2, varscan2
- PARP4 | c.3565C>A p.P1189T | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT tolerated (0.24); PolyPhen benign (0.188); catalogued as COSV101131991, COSV67964782; called by muse, mutect2, varscan2
- PATJ | c.690C>G p.S230R | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.046); catalogued as COSV100334847; called by muse, varscan2
- PCDH15 | c.5723T>C p.L1908P | Missense Mutation (SNP) | VAF 28/111 reads (25%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as COSV100226453, COSV57308853; called by muse, mutect2, varscan2
- PCDH15 | c.5342C>T p.P1781L | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as COSV100226457; called by muse, mutect2, varscan2
- PCDH17 | c.1447G>A p.E483K | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV64972204; called by muse, mutect2, varscan2
- PCDH18 | c.3340G>A p.E1114K | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV61267754; called by muse, mutect2, varscan2
- PCDH18 | c.416G>A p.R139K | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.97); catalogued as COSV100787481; called by muse, mutect2, varscan2
- PCDH18 | c.59C>T p.S20F | Missense Mutation (SNP) | VAF 30/88 reads (34%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV100787483; called by muse, mutect2, varscan2
- PCDHA11 | c.914G>A p.G305E | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.832); catalogued as COSV56481975; called by muse, mutect2, varscan2
- PCDHA13 | c.986C>A p.P329Q | Missense Mutation (SNP) | VAF 60/98 reads (61%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.824); catalogued as COSV99169385; called by muse, mutect2, varscan2
- PCDHB16 | c.1217A>T p.E406V | Missense Mutation (SNP) | VAF 32/55 reads (58%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.036); catalogued as CM125276, COSV99502703; called by muse, mutect2, varscan2
- PCDHGA4 | c.1381C>T p.P461S | Missense Mutation (SNP) | VAF 24/36 reads (67%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV99545433; called by muse, mutect2, varscan2
- PCLO | c.14380T>C p.Y4794H | Missense Mutation (SNP) | VAF 17/26 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs777115795, COSV100436795; called by muse, mutect2, varscan2
- PCLO | c.12241C>T p.R4081* | Nonsense Mutation (SNP) | VAF 6/19 reads (32%) | catalogued as COSV61614924; called by muse, mutect2, varscan2
- PCOLCE2 | c.1034G>A p.G345E | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.951); catalogued as COSV55998143; called by muse, mutect2, varscan2
- PDE4B | c.308C>T p.P103L | Missense Mutation (SNP) | VAF 96/264 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as COSV100304698; called by muse, mutect2, varscan2
- PDGFC | c.946G>A p.G316S | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT tolerated (0.12); PolyPhen probably damaging (1); catalogued as rs1455196232, COSV99924811, COSV99926064; called by muse, mutect2, varscan2
- PDPN | c.263G>A p.S88N (on ENST00000621990; = p.S164N on NM_006474.4) | Missense Mutation (SNP) | VAF 33/133 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.4); catalogued as COSV99611119, COSV99611796; called by muse, mutect2, varscan2
- PEG3 | c.2924G>A p.G975E | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs1424141414, COSV99690161; called by muse, mutect2, varscan2
- PENK | c.116G>C p.R39P | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.022); catalogued as COSV100152454; called by muse, mutect2, varscan2
- PHACTR3 | c.256G>A p.E86K | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1332569140, COSV63025673; called by muse, mutect2, varscan2
- PHC1 | c.1994C>T p.P665L | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV101418695; called by muse, mutect2, varscan2
- PHC3 | c.1430C>T p.P477L (on ENST00000494943 / NM_001308116.2; = p.P489L on NM_024947.4) | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.026); catalogued as COSV101520186; called by muse, mutect2, varscan2
- PHC3 | c.1429C>T p.P477S (on ENST00000494943 / NM_001308116.2; = p.P489S on NM_024947.4) | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as rs760376338, COSV101520187; called by muse, mutect2, varscan2
- PHIP | c.3893G>A p.R1298Q | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.788); catalogued as rs1207047989, COSV51502271; called by muse, mutect2, varscan2
- PHKB | c.827G>A p.R276K | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); catalogued as COSV100068308; called by muse, mutect2, varscan2
- PHLDB2 | c.1807G>A p.E603K | Missense Mutation (SNP) | VAF 28/84 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.795); catalogued as COSV67310370; called by muse, mutect2, varscan2
- PI4KA | c.2117C>A p.S706Y | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV99748248; called by muse, mutect2
- PIGQ | c.2071C>T p.P691S | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV99216447; called by muse, mutect2, varscan2
- PIK3C2G | c.1018G>A p.E340K | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs1050171572, COSV99853629; called by muse, mutect2, varscan2
- PIK3C2G | c.4036C>T p.L1346F (on ENST00000676171; = p.L1305F on NM_004570.5) | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV56804924, COSV56826926; called by muse, mutect2, varscan2
- PIP5K1C | c.1613G>A p.R538Q | Missense Mutation (SNP) | VAF 38/106 reads (36%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.539); catalogued as rs762902576, COSV100095098, COSV58951776; called by muse, mutect2, varscan2
- PITPNC1 | c.770C>T p.S257F | Missense Mutation (SNP) | VAF 30/153 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV100083481, COSV100084024; called by muse, mutect2, varscan2
- PITPNM3 | c.2029G>A p.E677K | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.141); catalogued as COSV99338948; called by muse, mutect2, varscan2
- PKHD1L1 | c.6244C>T p.P2082S | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated (0.71); PolyPhen benign (0.009); catalogued as COSV65742548; called by muse, mutect2, varscan2
- PKHD1L1 | c.7849C>T p.H2617Y | Missense Mutation (SNP) | VAF 30/100 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV101006725; called by muse, mutect2, varscan2
- PLA2G4E | c.1405G>A p.E469K | Missense Mutation (SNP) | VAF 21/84 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.597); catalogued as COSV101268630; called by muse, mutect2, varscan2
- PLCB1 | c.2237G>A p.R746K | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.981); catalogued as COSV100571900; called by muse, mutect2, varscan2
- PLCG2 | c.1897G>A p.D633N | Missense Mutation (SNP) | VAF 28/137 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.73); catalogued as COSV63875602; called by muse, mutect2, varscan2
- PLCXD3 | c.194T>A p.F65Y | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV100126188; called by muse, mutect2, varscan2
- PLEKHA4 | c.1771G>A p.A591T | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV99613085; called by muse, mutect2, varscan2
- PLEKHB2 | c.423G>A p.E141= | Splice Region (SNP) | VAF 17/54 reads (31%) | catalogued as COSV99301816; called by muse, mutect2, varscan2
- PLEKHB2 | c.423+1G>A p.X141_splice | Splice Site (SNP) | VAF 17/54 reads (31%) | catalogued as COSV52175360, COSV99301821; called by muse, mutect2, varscan2
- PLEKHG1 | c.3595C>T p.P1199S | Missense Mutation (SNP) | VAF 23/80 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.162); catalogued as COSV100651837; called by muse, mutect2, varscan2
- PLEKHM2 | c.1729C>T p.P577S | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); catalogued as rs773278094, COSV101009193; called by muse, varscan2
- PLEKHS1 | c.674C>T p.S225F (on ENST00000369310 / NM_182601.1; = p.S231F on NM_024889.5) | Missense Mutation (SNP) | VAF 29/106 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV100613287; called by muse, mutect2, varscan2
- PLXNA4 | c.4284G>A p.R1428= | Splice Region (SNP) | VAF 3/15 reads (20%) | catalogued as COSV100326518, COSV58110440; called by muse, mutect2
979 further variants in this file (404 protein-altering or splice-affecting, 523 silent, 52 other) are not listed here.
